Somatic mutation profile of tumor specimen TCGA-D3-A8GM-06A (aliquot TCGA-D3-A8GM-06A-11D-A372-08) from TCGA case TCGA-D3-A8GM, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 75.0 years (27,378 days).
Specimen TCGA-D3-A8GM-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a608b17a-e0de-4036-b5e3-666441e1ecec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A8GM-10A (Blood Derived Normal), aliquot TCGA-D3-A8GM-10A-01D-A375-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e6ee0ea-d3cc-473b-adff-7fe22e3f81c9

The open-access MAF lists 4,613 somatic variants for this specimen: 3,060 protein-altering or splice-affecting, 1,444 silent, 109 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2,620, Silent 1,444, Nonsense Mutation 208, Frame Shift Del 95, Splice Site 51, Intron 50, Frame Shift Ins 42, Splice Region 34, RNA 32, 5'Flank 8, 3'Flank 7, 3'UTR 6.

Variants (750 of 4,613; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC011462.1 | c.1066C>T p.Q356* | Nonsense Mutation (SNP) | VAF 23/56 reads (41%) | catalogued as rs398123513, COSV99524485; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CFTR | c.171G>A p.W57* | Nonsense Mutation (SNP) | VAF 23/208 reads (11%) | catalogued as rs121909025, CM994782, COSV50095887, COSV99134689; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL3A1 | c.2941G>A p.G981R | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587779449, CM1412680, CM1412681, COSV100482720; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL4A5 | c.892G>A p.G298S | Missense Mutation (SNP) | VAF 49/72 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104886080, CM960348, COSV100087053; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DCC | c.2414G>A p.G805E | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519055, COSV100498925; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DHX30 | c.1478G>A p.R493H (on ENST00000445061 / NM_138615.3; = p.R454H on NM_014966.3) | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519436, COSV53140099; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DNAH5 | c.10615C>T p.R3539C | Missense Mutation (SNP) | VAF 56/305 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1304504006, CM091938, COSV54205813; ClinVar: likely pathogenic; called by muse, varscan2
- FBN1 | c.2581C>T p.R861* | Nonsense Mutation (SNP) | VAF 12/103 reads (12%) | catalogued as rs140583, CM972802, COSV57319926; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GALT | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.527); catalogued as rs111033735, CM950551, COSV66593644; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GLB1 | c.1577del p.G526Afs*74 | Frame Shift Del (DEL) | VAF 12/71 reads (17%) | catalogued as rs794729217; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- IKZF1 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 11/37 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.212); catalogued as rs759124417, COSV58782650, COSV58783750; called by muse, mutect2, varscan2
- KIT | c.1676T>C p.V559A | Missense Mutation (SNP) | VAF 47/120 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as rs121913517, CM013551, COSV55386973, COSV55388782, COSV55393324; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MECOM | c.2542C>T p.R848* (on ENST00000468789 / NM_001105078.4; = p.R1036* on NM_004991.4) | Nonsense Mutation (SNP) | VAF 47/139 reads (34%) | catalogued as rs1560118923, COSV52968817; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MFRP | chr11:119345563 del G | 5'Flank (DEL) | VAF 11/53 reads (21%) | catalogued as rs587776596, CD052468, COSV64129114; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MSH2 | c.1384C>T p.Q462* | Nonsense Mutation (SNP) | VAF 17/65 reads (26%) | catalogued as rs876657701, COSV99253469; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PAH | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199475694, CM1111672, COSV100187785; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RAD50 | c.2165del p.K722Rfs*14 | Frame Shift Del (DEL) | VAF 49/138 reads (36%) | catalogued as rs397507178, COSV54758496; ClinVar: pathogenic; called by mutect2, varscan2
- RPE65 | c.1067del p.N356Mfs*17 | Frame Shift Del (DEL) | VAF 18/86 reads (21%) | catalogued as rs281865520, CD972436; ClinVar: not provided / pathogenic; called by mutect2, varscan2
- RYR1 | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.93); catalogued as rs118192160, CM061939, CM140861, COSV62087706, COSV62099686; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SDR9C7 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs538068583, COSV53288872; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP63 | c.1825G>A p.E609K | Missense Mutation (SNP) | VAF 24/79 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.205); catalogued as rs142762485, COSV53196450; called by muse, varscan2
- TSC2 | c.3412C>T p.R1138* | Nonsense Mutation (SNP) | VAF 39/145 reads (27%) | catalogued as rs45451497, CM992687, COSV54761190; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- TSC2 | c.5024C>T p.P1675L | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs45483392, CM971532, COSV51912177, COSV51927085, COSV99237457; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- WARS2 | c.715C>T p.R239* | Nonsense Mutation (SNP) | VAF 58/195 reads (30%) | catalogued as rs757600616, COSV99346123; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.1090A>G p.R364G | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV100228659; called by muse, mutect2, varscan2
- AADAC | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 49/144 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51760867; called by muse, mutect2, varscan2
- AADAT | c.592C>T p.P198S | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100528587; called by muse, mutect2, varscan2
- AATK | c.2099C>T p.S700F (on ENST00000326724 / NM_001080395.3; = p.S597F on NM_004920.2) | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs1361049202, COSV100352610; called by muse, mutect2, varscan2
- AATK | c.1906C>T p.P636S (on ENST00000326724 / NM_001080395.3; = p.P533S on NM_004920.2) | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs769926715, COSV100352611; called by muse, varscan2
- ABAT | c.533G>A p.W178* | Nonsense Mutation (SNP) | VAF 8/37 reads (22%) | catalogued as COSV99190903; called by muse, mutect2, varscan2
- ABAT | c.642G>A p.M214I | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.026); catalogued as COSV99190904; called by muse, mutect2, varscan2
- ABCA12 | c.4996A>T p.K1666* (on ENST00000272895 / NM_173076.3; = p.K1348* on NM_015657.3) | Nonsense Mutation (SNP) | VAF 7/43 reads (16%) | catalogued as COSV99789090; called by muse, mutect2, varscan2
- ABCA12 | c.1258C>T p.P420S (on ENST00000272895 / NM_173076.3; = p.P102S on NM_015657.3) | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs1297612225, COSV55952615; called by muse, mutect2, varscan2
- ABCA2 | c.154C>T p.Q52* | Nonsense Mutation (SNP) | VAF 9/22 reads (41%) | catalogued as rs780395695; called by muse, mutect2
- ABCA3 | c.3467C>T p.P1156L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV100068184; called by muse, mutect2, varscan2
- ABCA4 | c.4682C>T p.S1561F | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV64671594, COSV64674573; called by muse, mutect2, varscan2
- ABCA4 | c.1756G>A p.D586N | Missense Mutation (SNP) | VAF 158/409 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.374); catalogued as COSV100933070; called by muse, mutect2, varscan2
- ABCA6 | c.4616+2T>G p.X1539_splice | Splice Site (SNP) | VAF 98/266 reads (37%) | catalogued as COSV99446099; called by muse, varscan2
- ABCA6 | c.3381T>A p.S1127R | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.06); catalogued as rs1393688557, COSV99446101; called by muse, mutect2, varscan2
- ABCA7 | c.851G>A p.W284* | Nonsense Mutation (SNP) | VAF 15/73 reads (21%) | catalogued as rs1312063413, COSV99565387; called by muse, mutect2, varscan2
- ABCA7 | c.2354C>T p.P785L | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs1448536466, COSV54037379; called by muse, varscan2
- ABCA7 | c.5653C>T p.R1885C | Missense Mutation (SNP) | VAF 39/173 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs149423196; called by muse, mutect2, varscan2
- ABCA9 | c.3751C>T p.P1251S | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.441); catalogued as COSV100382829; called by muse, mutect2, varscan2
- ABCB1 | c.3043del p.T1015Pfs*3 | Frame Shift Del (DEL) | VAF 16/86 reads (19%) | catalogued as COSV55964223; called by mutect2, pindel, varscan2
- ABCB11 | c.1768G>A p.D590N | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99791769; called by muse, mutect2, varscan2
- ABCC10 | c.2647G>A p.G883S (on ENST00000372530 / NM_001198934.2; = p.G855S on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.058); catalogued as COSV99766926; called by muse, mutect2, varscan2
- ABCC6 | c.2009C>T p.S670F | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99228348; called by mutect2, varscan2
- ABCC9 | c.3094C>T p.Q1032* | Nonsense Mutation (SNP) | VAF 25/74 reads (34%) | catalogued as rs1269392352, COSV99685036; called by muse, mutect2, varscan2
- ABCD4 | c.1448C>T p.P483L | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV100084118, COSV100084470; called by muse, mutect2, varscan2
- ABCE1 | c.1606G>A p.D536N | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.197); catalogued as COSV56848779, COSV99668472; called by muse, mutect2, varscan2
- ABCF2 | c.868G>C p.G290R | Missense Mutation (SNP) | VAF 146/400 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99734174; called by muse, mutect2, varscan2
- ABLIM1 | c.2194C>T p.L732F | Missense Mutation (SNP) | VAF 83/156 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.492); catalogued as COSV99521718; called by muse, mutect2, varscan2
- ABRA | c.114T>A p.N38K | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.121); catalogued as COSV100357504; called by muse, mutect2, varscan2
- ABT1 | c.423T>G p.D141E | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.771); catalogued as COSV99223161; called by muse, mutect2, varscan2
- AC004922.1 | c.904C>T p.R302C | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.818); catalogued as rs1349181083, COSV53555502; called by muse, mutect2, varscan2
- AC139530.2 | c.241G>T p.D81Y | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.042); catalogued as COSV100230336; called by muse, mutect2, varscan2
- ACADVL | c.1425G>T p.Q475H | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV50038959; called by muse, mutect2, varscan2
- ACAN | c.4360G>A p.G1454R | Missense Mutation (SNP) | VAF 62/246 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1209165088, COSV61363684; called by muse, varscan2
- ACAN | c.4361G>A p.G1454E | Missense Mutation (SNP) | VAF 60/242 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100717462; called by muse, varscan2
- ACAN | c.5674C>T p.P1892S | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs767984963, COSV100717466; called by muse, mutect2, varscan2
- ACAN | c.6019G>A p.D2007N | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs753033186, COSV61361206; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACAN | c.6391G>A p.E2131K | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.122); catalogued as COSV61362268; called by muse, mutect2, varscan2
- ACAN | c.6856G>A p.E2286K | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.94); PolyPhen possibly damaging (0.647); catalogued as rs1567189232, COSV100717474; called by muse, mutect2, varscan2
- ACAN | c.7259G>A p.R2420K (on ENST00000560601 / NM_001369268.1; = p.R2344K on NM_001135.3) | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.036); catalogued as rs1192450564, COSV100717476; called by muse, mutect2, varscan2
- ACAP2 | c.1381C>T p.P461S | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1210110319, COSV100461713; called by muse, varscan2
- ACP3 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.259); catalogued as COSV100313243; called by muse, mutect2, varscan2
- ACSBG1 | c.1984G>A p.E662K | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as rs779018573, COSV51906355, COSV99357242; called by muse, mutect2, varscan2
- ACSM2B | c.1690C>T p.R564* | Nonsense Mutation (SNP) | VAF 51/236 reads (22%) | catalogued as rs374858896; called by muse, mutect2, varscan2
- ACSM5 | c.1187C>T p.S396F | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as COSV100088616; called by muse, mutect2, varscan2
- ACTA2 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.839); catalogued as COSV99826978; called by muse, mutect2, varscan2
- ACTL6B | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.9); PolyPhen benign (0.012); catalogued as COSV99355484; called by muse, mutect2, varscan2
- ACTL6B | c.233G>A p.G78E | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.243); catalogued as COSV50513893; called by muse, mutect2, varscan2
- ACTL7B | c.913C>T p.P305S | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101012504; called by muse, mutect2, varscan2
- ADAD1 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT tolerated (0.57); PolyPhen benign (0.021); catalogued as COSV99635314; called by muse, mutect2, varscan2
- ADAM10 | c.573G>T p.E191D | Missense Mutation (SNP) | VAF 54/201 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV99545791; called by muse, mutect2, varscan2
- ADAM15 | c.616C>T p.R206W | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772205386, COSV55056483; called by muse, mutect2, varscan2
- ADAM18 | c.1607C>T p.S536L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.544); catalogued as COSV55846857; called by muse, mutect2
- ADAM2 | c.610A>G p.K204E | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99697007; called by muse, mutect2, varscan2
- ADAM21 | c.1205A>T p.E402V | Missense Mutation (SNP) | VAF 61/141 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV99960704; called by muse, mutect2, varscan2
- ADAM22 | c.992C>T p.S331L | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); catalogued as rs370014529, COSV55969068; called by muse, mutect2, varscan2
- ADAM22 | c.1069G>A p.V357M | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773805839, COSV55975866; called by muse, mutect2, varscan2
- ADAM28 | c.350C>T p.S117F | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56100312, COSV99738185; called by muse, mutect2, varscan2
- ADAM30 | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 63/157 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.036); catalogued as COSV65561014, COSV65562307; called by muse, mutect2, varscan2
- ADAM7 | c.995G>A p.R332K | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.94); PolyPhen benign (0.191); catalogued as COSV51537081; called by muse, mutect2, varscan2
- ADAM7 | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99443322; called by muse, mutect2, varscan2
- ADAMDEC1 | c.910G>A p.D304N | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.941); catalogued as rs1351755384, COSV99835912; called by muse, mutect2, varscan2
- ADAMTS10 | c.3253C>T p.Q1085* | Nonsense Mutation (SNP) | VAF 5/19 reads (26%) | catalogued as COSV54352331; called by muse, mutect2
- ADAMTS13 | c.1301A>G p.N434S | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs781993871, COSV100747007; called by muse, mutect2, varscan2
- ADAMTS18 | c.3188A>G p.E1063G | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV51417603; called by muse, mutect2
- ADAMTS18 | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99271760; called by muse, mutect2, varscan2
- ADAMTS19 | c.2704G>A p.E902K | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as COSV50799572; called by muse, mutect2, varscan2
- ADAMTS19 | c.2794G>A p.D932N | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.686); catalogued as COSV99176773; called by muse, mutect2, varscan2
- ADAMTS20 | c.5387C>T p.A1796V | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs1169232633, COSV101239080; called by muse, mutect2, varscan2
- ADAMTS20 | c.4702G>A p.E1568K | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.767); catalogued as rs925998386, COSV67133124; called by muse, mutect2, varscan2
- ADAMTS6 | c.3271T>G p.Y1091D | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100068302; called by muse, mutect2, varscan2
- ADAMTS6 | c.1901G>A p.G634E | Missense Mutation (SNP) | VAF 51/118 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as rs1344649190, COSV66857938; called by muse, mutect2, varscan2
- ADAMTS6 | c.112T>C p.Y38H | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0.251); catalogued as COSV101124863; called by muse, mutect2, varscan2
- ADAMTS7 | c.2941C>T p.Q981* | Nonsense Mutation (SNP) | VAF 22/65 reads (34%) | catalogued as COSV101183056; called by muse, mutect2, varscan2
- ADAMTS9 | c.2461C>T p.R821C | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs1464529267, COSV55785517; called by muse, mutect2, varscan2
- ADAMTS9 | c.1118C>T p.S373L | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs746299995, COSV55782937; called by muse, mutect2, varscan2
- ADAMTSL1 | c.913G>A p.D305N | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52820134, COSV99441645; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4123dup p.Q1375Pfs*53 | Frame Shift Ins (INS) | VAF 10/54 reads (19%) | catalogued as rs758913277; called by mutect2, varscan2
- ADAMTSL4 | c.980G>A p.R327H | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs774556202, COSV99646881; called by muse, mutect2, varscan2
- ADAMTSL4 | c.1667G>A p.R556Q | Missense Mutation (SNP) | VAF 84/171 reads (49%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs773684053, COSV55006448; called by muse, mutect2, varscan2
- ADCY1 | c.3231T>A p.F1077L | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.005); catalogued as COSV99811580; called by muse, mutect2, varscan2
- ADCY7 | c.761A>G p.K254R | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.023); catalogued as rs756602945, COSV99575791; called by muse, mutect2, varscan2
- ADCY8 | c.2093C>T p.S698F | Missense Mutation (SNP) | VAF 38/194 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as COSV99651380; called by muse, mutect2, varscan2
- ADD2 | c.1978G>A p.E660K | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as COSV52459970; called by muse, mutect2, varscan2
- ADGRA1 | c.1177G>A p.G393R | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); catalogued as rs1356315581, COSV100811008; called by muse, mutect2, varscan2
- ADGRA2 | c.933T>C p.S311= | Splice Region (SNP) | VAF 3/37 reads (8%) | catalogued as COSV100177694; called by muse, mutect2
- ADGRB1 | c.3634G>A p.G1212S | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.059); catalogued as rs1476696490, COSV100029405; called by muse, mutect2
- ADGRE2 | c.2065C>T p.L689F | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs774513835, COSV59694315; called by muse, mutect2, varscan2
- ADGRE2 | c.1222C>T p.P408S | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.258); catalogued as COSV100215821; called by muse, mutect2, varscan2
- ADGRF1 | c.119A>G p.K40R | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV100982565; called by muse, mutect2, varscan2
- ADGRF2 | c.1316A>C p.H439P (on ENST00000296862 / NM_001368115.2; = p.H371P on NM_153839.7) | Missense Mutation (SNP) | VAF 46/195 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.268); catalogued as COSV99730923; called by muse, mutect2, varscan2
- ADGRF5 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.048); catalogued as COSV99345171; called by muse, mutect2, varscan2
- ADGRL2 | c.337C>T p.P113S | Missense Mutation (SNP) | VAF 69/261 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV54663095; called by muse, mutect2, varscan2
- ADGRV1 | c.2834G>A p.G945E | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs373001982; called by muse, mutect2, varscan2
- ADGRV1 | c.3253G>A p.D1085N | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.963); catalogued as rs748413150, COSV67980503; called by muse, mutect2, varscan2
- ADGRV1 | c.5725C>T p.P1909S | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.7); PolyPhen benign (0.03); catalogued as rs781507717, COSV67991286; called by muse, mutect2, varscan2
- ADGRV1 | c.6358C>T p.L2120F | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV101315664; called by muse, mutect2, varscan2
- ADGRV1 | c.9878G>A p.R3293Q | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.029); catalogued as rs369319752; called by muse, mutect2, varscan2
- ADGRV1 | c.11722G>A p.D3908N | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.926); catalogued as rs749544658, COSV101316185, COSV67979351; called by muse, mutect2, varscan2
- ADGRV1 | c.16399G>A p.E5467K | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV101315667; called by muse, varscan2
- ADH1C | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 61/466 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.105); catalogued as COSV101565168, COSV101565175, COSV72463588; called by muse, mutect2, varscan2
- ADH6 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1358708729, COSV52955815; called by muse, mutect2, varscan2
- ADRA1A | c.1385A>T p.N462I | Missense Mutation (SNP) | VAF 46/203 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.38); catalogued as COSV99370324; called by muse, mutect2, varscan2
- ADRA2B | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1456731042, COSV69787678; called by muse, mutect2
- ADSS2 | c.1315C>T p.P439S | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs762699405, COSV100836817; called by muse, mutect2, varscan2
- AFF2 | c.2720G>A p.R907K | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as COSV99662736; called by muse, mutect2, varscan2
- AFF3 | c.2372C>G p.A791G | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV100418310; called by muse, mutect2, varscan2
- AFG3L2 | c.718C>T p.R240W | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as rs768999765, COSV99301663; ClinVar: likely benign; called by muse, mutect2, varscan2
- AGAP3 | c.70C>T p.Q24* (on ENST00000622464; = p.Q60* on NM_031946.7 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 10/21 reads (48%) | catalogued as COSV52543712; called by muse, mutect2, varscan2
- AGL | c.4594T>A p.L1532I | Missense Mutation (SNP) | VAF 87/193 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.303); catalogued as COSV99648807; called by muse, mutect2, varscan2
- AGTR1 | c.29G>A p.G10D | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV100836975; called by muse, mutect2, varscan2
- AGTR2 | c.338G>A p.G113E | Missense Mutation (SNP) | VAF 102/162 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100903548; called by muse, mutect2, varscan2
- AK7 | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as rs199700054, COSV50872491; called by muse, mutect2, varscan2
- AK9 | c.2774G>A p.R925K | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100393385, COSV58138579; called by muse, mutect2, varscan2
- AKAP6 | c.3844A>G p.S1282G | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs1439414658, COSV55224620; called by muse, mutect2, varscan2
- AKNA | c.3595G>A p.D1199N | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV99799945; called by muse, mutect2, varscan2
- AKR1C8P | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 74/243 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs868921765; called by muse, mutect2, varscan2
- AL121899.2 | c.248C>T p.P83L | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV101198421; called by muse, mutect2, varscan2
- AL645922.1 | c.953A>T p.N318I | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.432); catalogued as COSV100190900; called by muse, mutect2, varscan2
- ALDH1B1 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.6); catalogued as COSV100890905; called by muse, mutect2
- ALDH1B1 | c.1069C>T p.Q357* | Nonsense Mutation (SNP) | VAF 18/68 reads (26%) | catalogued as rs1168366777, COSV100890906; called by muse, mutect2, varscan2
- ALDH1L1 | c.2164G>A p.E722K | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV99856615; called by muse, mutect2, varscan2
- ALDH3A1 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.93); PolyPhen benign (0.012); catalogued as rs778654435, COSV99855688, COSV99855796; called by muse, mutect2, varscan2
- ALDH5A1 | c.1108G>A p.V370I | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as rs754091433, COSV62373108; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALDH8A1 | c.669G>T p.E223D | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99664543; called by muse, mutect2, varscan2
- ALK | c.2781del p.C928Afs*11 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | catalogued as rs772809305; called by mutect2, pindel, varscan2
- ALKBH3 | c.611T>A p.I204N | Missense Mutation (SNP) | VAF 73/160 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100236166; called by muse, mutect2, varscan2
- ALMS1 | c.4709C>T p.S1570F | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.359); catalogued as rs765461259, COSV100041700; called by muse, mutect2, varscan2
- ALOX15B | c.1957G>A p.E653K | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as COSV101205588; called by muse, mutect2, varscan2
- ALPK2 | c.2318C>T p.A773V | Missense Mutation (SNP) | VAF 57/121 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV64492916; called by muse, mutect2, varscan2
- ALPK2 | c.1636C>T p.P546S | Missense Mutation (SNP) | VAF 72/160 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.025); catalogued as COSV100864213; called by muse, mutect2, varscan2
- ALS2 | c.332T>C p.V111A | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV99968990; called by muse, mutect2, varscan2
- ALS2CL | c.2480C>T p.S827F | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100014659; called by muse, mutect2, varscan2
- AMDHD1 | c.1258G>A p.G420R | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99701292; called by muse, mutect2, varscan2
- AMER3 | c.776C>T p.S259L | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.421); catalogued as rs756210400, COSV100366172, COSV58465910; called by muse, mutect2, varscan2
- AMER3 | c.1321G>A p.D441N | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.812); catalogued as COSV58470840; called by muse, mutect2, varscan2
- AMIGO2 | c.1037G>A p.G346E | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99873508; called by muse, mutect2, varscan2
- AMMECR1L | c.485T>C p.L162P | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99761299; called by muse, mutect2, varscan2
- AMPD2 | c.1766C>T p.P589L | Missense Mutation (SNP) | VAF 52/224 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as rs1209648130, COSV99857492; called by muse, mutect2, varscan2
- AMY1C | c.1039C>T p.P347S | Missense Mutation (SNP) | VAF 49/241 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs748751804, COSV64407770; called by muse, mutect2, varscan2
- ANAPC1 | c.5075C>G p.S1692C | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100594597; called by muse, mutect2, varscan2
- ANAPC4 | c.2009C>T p.P670L | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV100193901; called by muse, mutect2, varscan2
- ANAPC5 | c.630del p.K210Nfs*14 | Frame Shift Del (DEL) | VAF 15/57 reads (26%) | catalogued as rs782363356; called by mutect2, pindel, varscan2
- ANGPT1 | c.1473G>A p.M491I | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV52449117; called by muse, mutect2, varscan2
- ANK1 | c.3991G>A p.D1331N | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV99224527; called by muse, mutect2, varscan2
- ANK1 | c.3965G>A p.R1322H | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as rs374960063; called by muse, mutect2, varscan2
- ANK1 | c.841C>T p.R281* | Nonsense Mutation (SNP) | VAF 20/103 reads (19%) | catalogued as COSV99224536; called by muse, mutect2, varscan2
- ANK3 | c.3056G>A p.R1019Q (on ENST00000280772 / NM_001320874.2; = p.R153Q on NM_001149.3) | Missense Mutation (SNP) | VAF 39/63 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1199911843, COSV99778997; called by muse, mutect2
- ANK3 | c.118G>A p.D40N | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1430387975; called by muse, mutect2
- ANKFY1 | c.514C>T p.Q172* | Nonsense Mutation (SNP) | VAF 18/94 reads (19%) | catalogued as COSV100492393; called by muse, mutect2, varscan2
- ANKRA2 | c.554C>T p.P185L | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99706972, COSV99707079; called by muse, mutect2, varscan2
- ANKRD11 | c.827C>T p.S276F | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99968711; called by muse, mutect2, varscan2
- ANKRD30A | c.1337G>A p.R446K (on ENST00000611781; = p.R390K on NM_052997.2) | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.93); PolyPhen benign (0.021); catalogued as COSV64610683; called by muse, mutect2, varscan2
- ANKRD35 | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1553740733, COSV100841666; called by muse, mutect2, varscan2
- ANKRD36B | c.857C>T p.S286F | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.134); catalogued as rs1295709142, COSV99308051; called by muse, mutect2, varscan2
- ANKRD50 | c.2182G>A p.A728T | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.073); catalogued as rs377077898; called by muse, mutect2, varscan2
- ANKRD6 | c.1108C>T p.H370Y | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.368); catalogued as COSV100329599; called by muse, mutect2, varscan2
- ANKS1B | c.3712G>A p.E1238K (on ENST00000547776 / NM_152788.4; = p.E404K on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.931); catalogued as COSV100243922; called by muse, mutect2, varscan2
- ANKS1B | c.2407G>A p.G803S | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.04); catalogued as rs369542708; called by muse, mutect2
- ANKS1B | c.1339C>T p.P447S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.78); PolyPhen benign (0.021); catalogued as rs745539676, COSV61335090; called by muse, mutect2, varscan2
- ANKS6 | c.1151C>T p.A384V | Missense Mutation (SNP) | VAF 55/138 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV100782243; called by muse, mutect2, varscan2
- ANO1 | c.2605G>A p.E869K | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV100796951, COSV100797139; called by muse, mutect2, varscan2
- ANO2 | c.412G>A p.D138N (on ENST00000356134 / NM_001278597.3; = p.D142N on NM_001278596.3) | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.217); catalogued as COSV100500187; called by muse, mutect2, varscan2
- ANO4 | c.383C>T p.S128F (on ENST00000392977 / NM_001286615.2; = p.S93F on NM_178826.4) | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.553); catalogued as rs199936621, COSV100152378; called by muse, mutect2, varscan2
- ANO4 | c.1618G>A p.A540T (on ENST00000392977 / NM_001286615.2; = p.A505T on NM_178826.4) | Missense Mutation (SNP) | VAF 42/194 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0.439); catalogued as rs1407940545, COSV100152387; called by muse, mutect2, varscan2
- ANO4 | c.1898G>T p.R633I (on ENST00000392977 / NM_001286615.2; = p.R598I on NM_178826.4) | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV100152390; called by muse, mutect2, varscan2
- ANO4 | c.2230G>A p.E744K (on ENST00000392977 / NM_001286615.2; = p.E709K on NM_178826.4) | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100152393; called by muse, mutect2, varscan2
- AOC1 | c.1663G>A p.E555K | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100710695; called by muse, mutect2, varscan2
- AOC2 | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 94/286 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs1263869519, COSV99513558; called by muse, mutect2, varscan2
- AOC2 | c.1045C>T p.Q349* | Nonsense Mutation (SNP) | VAF 62/177 reads (35%) | catalogued as COSV53199356; called by muse, mutect2, varscan2
- AOC2 | c.1721C>T p.S574F | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV53824523; called by muse, mutect2, varscan2
- AOC3 | c.919C>T p.P307S | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.017); catalogued as rs777916243, COSV99520045, COSV99520047; called by muse, mutect2, varscan2
- AOX1 | c.1705-1G>A p.X569_splice | Splice Site (SNP) | VAF 23/53 reads (43%) | catalogued as COSV101021833; called by muse, mutect2, varscan2
- AP1B1 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58018819; called by mutect2, varscan2
- AP4M1 | c.628G>A p.V210M | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs778667078, COSV57997243; called by muse, mutect2, varscan2
- APBB1 | c.683C>T p.S228F | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs764930193, COSV100193762; called by muse, mutect2, varscan2
- APBB2 | c.1465G>A p.V489M (on ENST00000295974 / NM_001166050.2; = p.V490M on NM_004307.2) | Missense Mutation (SNP) | VAF 62/142 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.438); catalogued as rs770065380, COSV55950698, COSV99922710; called by muse, mutect2, varscan2
- APOB | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99264521; called by muse, mutect2, varscan2
- APOBR | c.941C>T p.S314L | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as rs777683528, COSV100112367; called by muse, mutect2, varscan2
- APOL5 | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs750413929, COSV50768088; called by muse, mutect2, varscan2
- APP | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100695462; called by muse, mutect2, varscan2
- AQP4 | c.965C>T p.S322L | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.253); catalogued as COSV101270495; called by muse, mutect2, varscan2
- AQP7 | c.314G>A p.G105D | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99952385; called by muse, mutect2, varscan2
- AQP9 | c.98C>T p.T33M | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as rs755358483, COSV99582746; called by muse, mutect2, varscan2
- ARAP2 | c.3641-1G>A p.X1214_splice | Splice Site (SNP) | VAF 20/54 reads (37%) | catalogued as COSV100394312; called by muse, mutect2
- ARAP2 | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.312); catalogued as COSV100394314; called by muse, mutect2, varscan2
- ARFGEF3 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV99292804; called by muse, mutect2, varscan2
- ARHGAP15 | c.940G>A p.G314R | Missense Mutation (SNP) | VAF 68/213 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1467501919, COSV54521361; called by muse, mutect2, varscan2
- ARHGAP30 | c.1363C>T p.R455W | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs903282972, COSV100920166; called by muse, mutect2, varscan2
- ARHGAP31 | c.2140C>T p.P714S | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as rs753114484, COSV99956791; called by muse, mutect2, varscan2
- ARHGAP32 | c.1778C>T p.P593L (on ENST00000310343 / NM_001378025.1; = p.P244L on NM_014715.4) | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100087295; called by muse, mutect2, varscan2
- ARHGAP35 | c.2854C>T p.H952Y | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT tolerated (0.45); PolyPhen benign (0.132); catalogued as rs1297580031, COSV101350819; called by muse, mutect2, varscan2
- ARHGAP6 | c.1886G>A p.R629K | Missense Mutation (SNP) | VAF 21/30 reads (70%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.913); catalogued as rs72558045, COSV100272585; called by muse, mutect2, varscan2
- ARHGEF1 | c.1538C>T p.S513F | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs781854393, COSV100528917; called by muse, mutect2, varscan2
- ARHGEF12 | c.3488A>G p.K1163R | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.628); catalogued as rs1459038118, COSV100754760; called by muse, mutect2, varscan2
- ARHGEF25 | c.778G>T p.E260* | Nonsense Mutation (SNP) | VAF 19/67 reads (28%) | catalogued as COSV99677733; called by muse, mutect2, varscan2
- ARID1B | c.3545C>T p.P1182L | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99268026; called by muse, mutect2, varscan2
- ARL8A | c.441G>A p.M147I | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV99693228; called by muse, mutect2
- ARMC5 | c.2314C>T p.P772S | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.794); catalogued as COSV99192380; called by muse, mutect2, varscan2
- ARNT2 | c.1805C>T p.T602M | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as rs561326856, COSV57582233; called by muse, mutect2, varscan2
- ARRB2 | c.235G>A p.D79N | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99346973; called by muse, mutect2
- ARSJ | c.1736del p.K579Rfs*30 | Frame Shift Del (DEL) | VAF 14/38 reads (37%) | catalogued as rs753865255; called by mutect2, varscan2
- ARSL | c.1702C>T p.P568S | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); catalogued as COSV101140446; called by muse, mutect2, varscan2
- ART4 | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.329); catalogued as COSV99966860; called by muse, mutect2, varscan2
- ASAP2 | c.1023+1G>A p.X341_splice | Splice Site (SNP) | VAF 11/71 reads (15%) | catalogued as rs1558350706, COSV55633402; called by muse, mutect2, varscan2
- ASB5 | c.959C>T p.T320M | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); catalogued as rs562003791, COSV56669215; called by muse, mutect2, varscan2
- ASB5 | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT tolerated (0.35); PolyPhen benign (0.112); catalogued as COSV56668570; called by muse, mutect2, varscan2
- ASH1L | c.6232C>T p.R2078C (on ENST00000368346 / NM_001366177.2; = p.R2073C on NM_018489.3) | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as rs772388982, COSV64204956; called by muse, mutect2, varscan2
- ASH2L | c.1105C>T p.P369S | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51699264; called by muse, mutect2, varscan2
- ASIC3 | c.1215-1G>T p.X405_splice | Splice Site (SNP) | VAF 11/95 reads (12%) | catalogued as COSV99876743; called by muse, mutect2, varscan2
- ASIC5 | c.1010G>A p.G337E | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV73332835; called by muse, mutect2, varscan2
- ASMT | c.916C>T p.Q306* (on ENST00000381229; = p.Q334* on NM_004043.2 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 45/138 reads (33%) | catalogued as COSV101172430; called by muse, mutect2, varscan2
- ASPG | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs754105558, COSV101496364; called by muse, mutect2, varscan2
- ASPM | c.5227C>T p.L1743F | Missense Mutation (SNP) | VAF 119/240 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.445); catalogued as rs201956605; called by muse, mutect2, varscan2
- ASPM | c.4495C>T p.R1499W | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756067585, COSV54125044; called by muse, mutect2, varscan2
- ASPM | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 67/133 reads (50%) | SIFT tolerated (0.48); PolyPhen benign (0.024); catalogued as COSV54136551; called by muse, mutect2, varscan2
- ASPRV1 | c.337C>T p.P113S | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.286); catalogued as COSV100208433; called by muse, varscan2
- ASTE1 | c.1424A>G p.H475R | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as COSV99393708; called by muse, mutect2, varscan2
- ASTL | c.1103C>T p.S368F | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.086); catalogued as COSV100668296; called by muse, mutect2
- ASTN1 | c.361C>T p.H121Y | Missense Mutation (SNP) | VAF 96/217 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.898); catalogued as rs1485620000, COSV56081808; called by muse, mutect2, varscan2
- ASTN2 | c.3733G>A p.E1245K (on ENST00000313400 / NM_001365069.1; = p.E1194K on NM_014010.5) | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as COSV56000282; called by muse, mutect2, varscan2
- ASZ1 | c.98C>T p.T33M | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.191); catalogued as rs113501399, COSV52914600; called by muse, varscan2
- ASZ1 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.18); catalogued as COSV52912224; called by muse, varscan2
- ATAD5 | c.2340del p.K780Nfs*13 | Frame Shift Del (DEL) | VAF 28/216 reads (13%) | catalogued as rs1316249589; called by mutect2, pindel, varscan2
- ATF5 | c.704C>A p.A235D | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); catalogued as COSV100351877; called by muse, mutect2, varscan2
- ATG2B | c.6196C>T p.R2066W | Missense Mutation (SNP) | VAF 46/204 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761750367, COSV99951992; called by muse, mutect2, varscan2
- ATG7 | c.1969T>C p.Y657H | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100606958; called by muse, mutect2, varscan2
- ATL3 | c.1019C>T p.P340L | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100219769; called by muse, mutect2, varscan2
- ATM | c.1370G>A p.R457Q | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as rs780097986, COSV99588356; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATMIN | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100214555; called by muse, mutect2, varscan2
- ATOH1 | c.202A>G p.T68A | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT tolerated (1); PolyPhen benign (0.048); catalogued as COSV100024467; called by muse, mutect2, varscan2
- ATP11C | c.1568T>C p.M523T | Missense Mutation (SNP) | VAF 28/40 reads (70%) | SIFT deleterious (0); PolyPhen benign (0.278); catalogued as COSV100557643; called by muse, mutect2, varscan2
- ATP13A1 | c.2393del p.G798Afs*55 | Frame Shift Del (DEL) | VAF 5/26 reads (19%) | catalogued as rs1165294989; called by mutect2, pindel
- ATP13A3 | c.3131G>A p.C1044Y | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.147); catalogued as COSV99756571; called by muse, mutect2, varscan2
- ATP13A4 | c.2350G>A p.D784N | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.139); catalogued as COSV100710196; called by muse, mutect2, varscan2
- ATP13A4 | c.1049G>A p.G350E | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs768044159, COSV99794218; called by muse, mutect2, varscan2
- ATP13A4 | c.269T>A p.I90K | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT tolerated (0.96); PolyPhen benign (0.007); catalogued as COSV99794220; called by muse, varscan2
- ATP13A4 | c.258G>A p.W86* | Nonsense Mutation (SNP) | VAF 42/116 reads (36%) | catalogued as COSV99794226; called by muse, varscan2
- ATP13A5 | c.2419C>T p.Q807* | Nonsense Mutation (SNP) | VAF 16/60 reads (27%) | catalogued as rs1365286592, COSV100664888; called by muse, mutect2, varscan2
- ATP13A5 | c.1936G>A p.E646K | Missense Mutation (SNP) | VAF 39/150 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.052); catalogued as rs1265545592, COSV100664889; called by muse, mutect2, varscan2
- ATP13A5 | c.1094G>A p.R365Q | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as rs372618344; called by muse, varscan2
- ATP13A5 | c.815-1G>A p.X272_splice | Splice Site (SNP) | VAF 21/56 reads (38%) | catalogued as rs751974727, COSV100664892; called by muse, mutect2, varscan2
- ATP13A5 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 48/189 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0.033); catalogued as COSV100664694; called by muse, mutect2, varscan2
- ATP1A2 | c.2699G>A p.G900E | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100767696; called by muse, mutect2, varscan2
- ATP1A4 | c.244C>T p.R82* | Nonsense Mutation (SNP) | VAF 76/159 reads (48%) | catalogued as rs565184841, COSV100927423, COSV63625976; called by muse, mutect2
- ATP1A4 | c.2965C>T p.L989F | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.96); catalogued as COSV100927466; called by muse, mutect2, varscan2
- ATP2A3 | c.2722G>A p.E908K | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99988950; called by muse, mutect2
- ATP6V0A1 | c.718T>C p.F240L | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.422); catalogued as rs1278948627, COSV99230679; called by muse, mutect2, varscan2
- ATP6V0A4 | c.2006C>T p.S669F | Missense Mutation (SNP) | VAF 53/321 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.83); catalogued as COSV100022859; called by muse, mutect2, varscan2
- ATP6V0A4 | c.1387G>A p.G463S | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59481840; called by muse, mutect2, varscan2
- ATP6V1A | c.1580C>T p.P527L | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.099); catalogued as COSV99849962; called by muse, mutect2, varscan2
- ATP8B3 | c.896C>T p.S299F | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs1331677902, COSV100034211; called by muse, mutect2, varscan2
- ATP9A | c.1930G>A p.E644K | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.361); catalogued as COSV100124547; called by mutect2, varscan2
- ATRN | c.2101C>T p.H701Y | Missense Mutation (SNP) | VAF 33/161 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1366527803, COSV99496838; called by muse, mutect2, varscan2
- ATXN1 | c.998G>A p.R333Q | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.978); catalogued as rs773660245, COSV99784946; called by muse, mutect2, varscan2
- ATXN7L2 | c.560C>G p.P187R | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.047); catalogued as COSV100881314; called by muse, mutect2, varscan2
- AXDND1 | c.792G>A p.M264I | Missense Mutation (SNP) | VAF 67/120 reads (56%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV100858285; called by muse, mutect2, varscan2
- AXDND1 | c.1900G>A p.E634K | Missense Mutation (SNP) | VAF 52/104 reads (50%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs924042947, COSV62644892; called by muse, mutect2, varscan2
- AXL | c.2260G>A p.E754K (on ENST00000301178 / NM_021913.5; = p.E745K on NM_001699.6) | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56569908; called by muse, mutect2, varscan2
- AZIN2 | c.592C>T p.H198Y | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99613128; called by muse, mutect2, varscan2
- AZU1 | c.377A>G p.N126S | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as rs151205721; called by muse, mutect2, varscan2
- B3GAT1 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100437783; called by muse, mutect2, varscan2
- BACH1 | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99728049; called by muse, mutect2, varscan2
- BACH1 | c.227C>T p.P76L | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV99728052; called by muse, mutect2, varscan2
- BAHCC1 | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs376051584; called by muse, mutect2, varscan2
- BBS7 | c.1028C>T p.S343F | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as COSV104389928, COSV99144850; called by muse, mutect2, varscan2
- BCAN | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 60/125 reads (48%) | SIFT tolerated (0.39); PolyPhen benign (0.098); catalogued as COSV100227945; called by muse, mutect2, varscan2
- BCAR3 | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.904); catalogued as rs1435872626, COSV99550470; called by muse, mutect2, varscan2
- BCAT1 | c.939G>A p.M313I | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.871); catalogued as rs767669322, COSV99678313; called by muse, mutect2, varscan2
- BCDIN3D | c.25G>A p.G9R | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100445487; called by muse, mutect2, varscan2
- BCHE | c.1158dup p.P387Sfs*5 | Frame Shift Ins (INS) | VAF 8/58 reads (14%) | catalogued as rs767469658; called by mutect2, pindel, varscan2
- BCKDHB | c.612dup p.A205Cfs*28 | Frame Shift Ins (INS) | VAF 16/182 reads (9%) | catalogued as rs1210649507; called by mutect2, pindel
- BCKDK | c.1121G>A p.R374Q | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as rs748371469, COSV99570520, COSV99570779; called by muse, mutect2, varscan2
- BCL11A | c.2045C>T p.T682M (on ENST00000335712 / NM_001365609.1; = p.T716M on NM_018014.4) | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs765066558, COSV100185156; called by muse, mutect2, varscan2
- BCLAF3 | c.1547C>T p.S516L | Missense Mutation (SNP) | VAF 25/37 reads (68%) | SIFT tolerated (0.21); PolyPhen benign (0.022); catalogued as COSV100503245; called by muse, mutect2, varscan2
- BCOR | c.4761G>T p.Q1587H (on ENST00000378444 / NM_001123385.2; = p.Q1553H on NM_017745.6) | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs767974035, COSV100653052; called by muse, varscan2
- BCR | c.3544C>T p.L1182F | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as COSV100006155; called by muse, mutect2, varscan2
- BEND4 | c.1297G>A p.G433S | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs779411414, COSV101549729; called by muse, mutect2, varscan2
- BEND7 | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 51/184 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.015); catalogued as COSV100346502; called by muse, mutect2, varscan2
- BEST3 | c.1921G>A p.D641N | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.014); catalogued as COSV100437670; called by muse, mutect2, varscan2
- BEST4 | c.859T>C p.Y287H | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV100943994; called by muse, mutect2, varscan2
- BEST4 | c.206G>A p.C69Y | Missense Mutation (SNP) | VAF 32/238 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100943995; called by muse, mutect2, varscan2
- BLM | c.2746C>T p.L916F | Missense Mutation (SNP) | VAF 53/129 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs1424143421, COSV100757076; called by muse, mutect2, varscan2
- BLVRA | c.589C>T p.Q197* | Nonsense Mutation (SNP) | VAF 37/121 reads (31%) | catalogued as COSV55515189; called by muse, mutect2, varscan2
- BMP3 | c.653G>A p.G218E | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99261491; called by muse, mutect2, varscan2
- BMPER | c.1080G>A p.K360= | Splice Region (SNP) | VAF 23/79 reads (29%) | catalogued as rs776511170, COSV99779232; called by muse, mutect2, varscan2
- BMT2 | c.1145C>T p.S382L | Missense Mutation (SNP) | VAF 59/168 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as COSV99774501; called by muse, mutect2, varscan2
- BNC1 | c.225dup p.M76Hfs*17 | Frame Shift Ins (INS) | VAF 17/55 reads (31%) | catalogued as rs751941533; called by mutect2, varscan2
- BNIP5 | c.145C>T p.H49Y | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.211); catalogued as COSV101465125; called by muse, mutect2, varscan2
- BPIFA2 | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 68/143 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.148); catalogued as COSV53612375; called by muse, mutect2, varscan2
- BPIFB2 | c.555T>G p.N185K | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99401267; called by muse, mutect2, varscan2
- BPTF | c.7943A>G p.K2648R | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV100074412; called by muse, mutect2, varscan2
- BRAF | c.1817A>G p.Y606C (on ENST00000288602 / NM_001374244.1; = p.Y566C on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99955506; called by muse, mutect2, varscan2
- BRAP | c.1661G>A p.R554Q | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.715); catalogued as rs145317226; called by muse, mutect2, varscan2
- BRD4 | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.656); catalogued as rs369254108; called by muse, mutect2, varscan2
- BRF1 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100527007; called by muse, mutect2, varscan2
- BRINP3 | c.1729G>A p.G577R | Missense Mutation (SNP) | VAF 82/166 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66514596; called by muse, mutect2, varscan2
- BRIP1 | c.3508C>T p.L1170F | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.041); catalogued as COSV99369670; called by muse, mutect2, varscan2
- BRPF3 | c.2179G>A p.V727M | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1176850107, COSV60209912; called by muse, mutect2
- BRS3 | c.670G>A p.V224M | Missense Mutation (SNP) | VAF 47/71 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101036493; called by muse, mutect2, varscan2
- BSN | c.889C>T p.P297S | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs1421998729, COSV99607714; called by muse, mutect2, varscan2
- BSN | c.3869T>A p.F1290Y | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV99607720; called by muse, varscan2
- BSN | c.3953C>T p.A1318V | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as COSV99607724; called by muse, varscan2
- BTBD11 | c.2231G>A p.R744K (on ENST00000280758 / NM_001018072.2; = p.R281K on NM_001017523.2) | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV99775141; called by muse, mutect2, varscan2
- BTBD3 | c.976G>A p.A326T | Missense Mutation (SNP) | VAF 57/138 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV99655729; called by muse, mutect2, varscan2
- BTBD7 | c.2386C>T p.P796S | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs745781357, COSV58290104; called by muse, mutect2, varscan2
- BTF3 | c.214A>T p.R72* (on ENST00000380591 / NM_001037637.1; = p.R28* on NM_001207.4) | Nonsense Mutation (SNP) | VAF 38/89 reads (43%) | catalogued as rs1192476330, COSV100246657; called by muse, mutect2, varscan2
- BTG3 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.857); catalogued as COSV100336263; called by muse, mutect2, varscan2
- BTG4 | c.493C>T p.P165S | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100604415; called by muse, mutect2, varscan2
- BTN3A1 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99175694; called by muse, mutect2, varscan2
- BTN3A2 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 39/240 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62688216; called by muse, mutect2, varscan2
- BUB1 | c.1076C>A p.P359H | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs1443564848, COSV100241043; called by muse, mutect2, varscan2
- C10orf120 | c.293T>C p.L98S | Missense Mutation (SNP) | VAF 115/227 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs761737584, COSV100271567; called by muse, mutect2, varscan2
- C10orf71 | c.1088G>A p.G363E | Missense Mutation (SNP) | VAF 34/51 reads (67%) | SIFT tolerated (0.39); PolyPhen benign (0.013); catalogued as rs985271678, COSV100109959, COSV60505874; called by muse, mutect2, varscan2
- C10orf71 | c.2018C>T p.S673F | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.71); PolyPhen benign (0.246); catalogued as rs1233798319, COSV100109912, COSV100110009; called by muse, mutect2, varscan2
- C11orf42 | c.931G>A p.D311N | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs1189483632, COSV56413667; called by muse, varscan2
- C11orf53 | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as rs1424098211, COSV99724671; called by muse, mutect2, varscan2
- C12orf42 | c.950G>A p.G317D | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.466); catalogued as COSV100171946; called by muse, mutect2, varscan2
- C12orf56 | c.388C>T p.H130Y | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.094); catalogued as rs200860774, COSV61485348; called by muse, mutect2, varscan2
- C1QTNF1 | c.386G>A p.G129E | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59264441; called by muse, mutect2, varscan2
- C1QTNF8 | c.400C>T p.Q134* | Nonsense Mutation (SNP) | VAF 3/16 reads (19%) | catalogued as rs1346465914, COSV100116374; called by muse, mutect2
- C1orf158 | c.274C>T p.R92C | Missense Mutation (SNP) | VAF 91/183 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs368618094; called by muse, mutect2, varscan2
- C1orf43 | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 51/93 reads (55%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV55174155; called by muse, varscan2
- C22orf42 | c.626C>T p.S209F | Missense Mutation (SNP) | VAF 54/140 reads (39%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.683); catalogued as COSV101173296; called by muse, mutect2, varscan2
- C2CD3 | c.5091-1G>A p.X1697_splice | Splice Site (SNP) | VAF 31/71 reads (44%) | catalogued as COSV100486368; called by muse, mutect2, varscan2
- C2CD4A | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV100831030; called by muse, mutect2, varscan2
- C2orf78 | c.1945G>A p.G649R | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as COSV68518364; called by muse, mutect2, varscan2
- C3 | c.1820A>G p.K607R | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.94); catalogued as rs866657374, COSV99836301; called by muse, mutect2, varscan2
- C3orf22 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as rs1354821418, COSV100559512; called by muse, mutect2, varscan2
- C6 | c.1492C>T p.P498S | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.71); catalogued as COSV99666781; called by muse, mutect2, varscan2
- C6 | c.1409C>T p.S470F | Missense Mutation (SNP) | VAF 49/249 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.587); catalogued as rs10462014, COSV99666783; called by muse, mutect2, varscan2
- C6 | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 56/164 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.255); catalogued as COSV99666784; called by muse, varscan2
- C7 | c.1595G>A p.G532E | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100495589; called by muse, mutect2, varscan2
- C7 | c.1898T>C p.L633P | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.571); catalogued as COSV100495590; called by muse, mutect2, varscan2
- C7orf50 | c.535del p.L179Cfs*136 | Frame Shift Del (DEL) | VAF 11/40 reads (28%) | catalogued as rs750339990; called by mutect2, pindel, varscan2
- C7orf57 | c.167C>A p.P56H | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.794); catalogued as COSV100817212; called by muse, mutect2, varscan2
- C8B | c.1100G>A p.R367K | Missense Mutation (SNP) | VAF 66/129 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100980730; called by muse, mutect2, varscan2
- C8orf34 | c.749C>T p.S250L | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.985); catalogued as COSV100445200; called by muse, mutect2, varscan2
- C9 | c.536G>A p.G179E | Missense Mutation (SNP) | VAF 41/204 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54677083; called by muse, mutect2, varscan2
- C9 | c.535G>A p.G179R | Missense Mutation (SNP) | VAF 40/203 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54676126, COSV54678955; called by muse, mutect2, varscan2
- CA1 | c.514G>A p.G172S | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs749226165, COSV56279620, COSV99810071; called by muse, mutect2
- CA10 | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV99562137; called by muse, mutect2, varscan2
- CACNA1A | c.2357G>A p.R786Q | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); catalogued as rs1233611505, COSV64193651; called by muse, mutect2, varscan2
- CACNA1B | c.4660G>A p.E1554K | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as COSV53137457, COSV99496055; called by muse, varscan2
- CACNA1D | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.867); catalogued as COSV99857225; called by muse, mutect2, varscan2
- CACNA1D | c.1642C>T p.P548S (on ENST00000350061 / NM_001128840.3; = p.P568S on NM_000720.4) | Missense Mutation (SNP) | VAF 45/139 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.729); catalogued as COSV99857226; called by muse, mutect2, varscan2
- CACNA1E | c.3382G>A p.V1128M | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); catalogued as COSV100701590; called by muse, mutect2, varscan2
- CACNA1E | c.5089G>A p.D1697N | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.149); catalogued as rs768500940, COSV62387967, COSV62424409; called by muse, mutect2, varscan2
- CACNA1G | c.1158G>A p.M386I | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100661421; called by muse, mutect2, varscan2
- CACNA1G | c.3904C>T p.P1302S | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.168); catalogued as COSV100661425; called by muse, mutect2
- CACNA1S | c.5287C>T p.H1763Y | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.015); catalogued as COSV62940056, COSV62943245; called by muse, mutect2
- CACNA2D1 | c.1789G>A p.E597K (on ENST00000356253 / NM_001366867.1; = p.E578K on NM_000722.4) | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.044); catalogued as COSV100666277; called by muse, mutect2, varscan2
- CACNB2 | c.337A>G p.K113E (on ENST00000324631 / NM_201596.3; = p.K58E on NM_000724.4) | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99993640; called by muse, mutect2, varscan2
- CACNB2 | c.791C>T p.P264L (on ENST00000324631 / NM_201596.3; = p.P209L on NM_000724.4) | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV56632153, COSV99993645; called by muse, mutect2, varscan2
- CACNG7 | c.199C>T p.R67W | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.606); catalogued as rs778063503, COSV99711905; called by muse, mutect2, varscan2
- CACNG7 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 54/139 reads (39%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.039); catalogued as COSV99711908; called by muse, mutect2, varscan2
- CADM3 | c.665C>T p.S222F (on ENST00000368125 / NM_001127173.3; = p.S256F on NM_021189.5) | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.608); catalogued as rs867065366, COSV63683495; called by muse, mutect2, varscan2
- CADPS | c.3555C>T p.F1185= | Splice Region (SNP) | VAF 52/160 reads (33%) | catalogued as rs770554516, COSV51894992; called by muse, mutect2, varscan2
- CADPS | c.982C>T p.P328S | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs774869379, COSV51882766; called by muse, mutect2, varscan2
- CAGE1 | c.724G>A p.E242K (on ENST00000512086; = p.E106K on NM_205864.3) | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as COSV99699467; called by muse, mutect2, varscan2
- CALCR | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 49/186 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.187); catalogued as rs144560846; called by muse, mutect2, varscan2
- CALHM1 | c.550T>A p.S184T | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100324172; called by muse, mutect2, varscan2
- CAMK2D | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.221); catalogued as COSV99593600; called by muse, mutect2, varscan2
- CAPN15 | c.2071C>T p.L691F | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1417919392, COSV99562289; called by muse, mutect2, varscan2
- CARD11 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 75/221 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV101210606; called by muse, mutect2, varscan2
- CARD11 | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100712220; called by muse, mutect2, varscan2
- CARD14 | c.2300C>T p.P767L | Missense Mutation (SNP) | VAF 2/16 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV100712512; called by muse, mutect2
- CARD9 | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.135); catalogued as rs767361965, COSV59998504; called by muse, mutect2, varscan2
- CARD9 | c.861G>A p.W287* | Nonsense Mutation (SNP) | VAF 10/22 reads (45%) | catalogued as COSV100261056; called by muse, varscan2
- CASC3 | c.1231C>T p.R411* | Nonsense Mutation (SNP) | VAF 7/120 reads (6%) | catalogued as COSV99229724; called by muse, mutect2
- CASR | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.693); catalogued as COSV99948639; called by muse, mutect2, varscan2
- CASS4 | c.593C>T p.P198L | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.092); catalogued as rs1031397464, COSV100824591; called by muse, mutect2, varscan2
- CASZ1 | c.4662C>G p.S1554R | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV100985134, COSV65457186; called by muse, mutect2, varscan2
- CATSPERD | c.1902G>A p.M634I | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58464338; called by muse, mutect2, varscan2
- CAV1 | c.329C>T p.P110L | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs1203265205, COSV61953954; called by muse, mutect2, varscan2
- CBFA2T2 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs146788442; called by muse, mutect2, varscan2
- CBL | c.369G>A p.M123I | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV50629733; called by muse, mutect2, varscan2
- CBL | c.1249C>T p.P417S | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867564832, COSV50631687, COSV50635445; called by muse, mutect2, varscan2
- CBLL2 | c.424C>T p.R142* | Nonsense Mutation (SNP) | VAF 31/56 reads (55%) | catalogued as rs146331121, COSV100081518; called by muse, mutect2, varscan2
- CBLN2 | c.667C>T p.P223S | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs868142587, COSV54050532; called by muse, mutect2, varscan2
- CBR4 | c.692G>A p.G231E | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100085775; called by muse, mutect2, varscan2
- CBX8 | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.053); catalogued as rs1339876348, COSV53935633; called by muse, mutect2, varscan2
- CCBE1 | c.812G>A p.G271D | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV101232799; called by muse, mutect2, varscan2
- CCDC102B | c.811T>A p.L271I | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.278); catalogued as COSV100102802; called by muse, mutect2, varscan2
- CCDC127 | c.440G>T p.R147M | Missense Mutation (SNP) | VAF 13/150 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.24); catalogued as COSV99722914; called by muse, mutect2
- CCDC138 | c.1928A>T p.N643I | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99718930; called by muse, mutect2, varscan2
- CCDC148 | c.845G>A p.R282K | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.423); catalogued as COSV99319969; called by muse, mutect2, varscan2
- CCDC151 | c.619C>T p.R207W | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1167009347, COSV62698407; called by muse, mutect2, varscan2
- CCDC170 | c.1408C>T p.R470C | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs267600858, COSV53337046; called by muse, mutect2, varscan2
- CCDC180 | c.1155G>T p.E385D | Missense Mutation (SNP) | VAF 12/141 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs1054248214, COSV100826622; called by muse, mutect2
- CCDC22 | c.1381C>T p.R461W | Missense Mutation (SNP) | VAF 14/17 reads (82%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1204203581, COSV100873113; called by muse, mutect2, varscan2
- CCDC28A | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.915); catalogued as COSV100236379; called by muse, mutect2, varscan2
- CCDC28A | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.23); catalogued as rs373972930, COSV60425332; called by muse, mutect2, varscan2
- CCDC60 | c.667C>T p.P223S | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV59548198; called by muse, mutect2, varscan2
- CCDC73 | c.1341del p.E448Kfs*5 | Frame Shift Del (DEL) | VAF 10/64 reads (16%) | catalogued as rs747079826; called by mutect2, varscan2
- CCDC85A | c.1424G>A p.G475E | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.996); catalogued as COSV101339422; called by muse, mutect2, varscan2
- CCDC9B | c.932G>A p.R311Q | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as rs1200397860, COSV101233494; called by muse, mutect2, varscan2
- CCER1 | c.1156C>T p.P386S | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.132); catalogued as COSV100726971, COSV100727016; called by muse, mutect2, varscan2
- CCNJL | c.578C>T p.P193L | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57445038, COSV99979346; called by muse, mutect2, varscan2
- CCR9 | c.1048G>A p.E350K (on ENST00000357632 / NM_031200.3; = p.E338K on NM_006641.4) | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.052); catalogued as rs554786336, COSV100591632; called by muse, mutect2, varscan2
- CD101 | c.2270C>T p.S757F | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99869322; called by muse, mutect2, varscan2
- CD109 | c.4090C>T p.P1364S | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.18); catalogued as COSV99753013; called by muse, mutect2, varscan2
- CD163L1 | c.3950G>A p.G1317E | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867081460, COSV58011299; called by muse, mutect2, varscan2
- CD163L1 | c.2889G>A p.W963* | Nonsense Mutation (SNP) | VAF 9/58 reads (16%) | catalogued as rs865810043, COSV100549842; called by muse, mutect2, varscan2
- CD163L1 | c.2135G>A p.G712E | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs867073039, COSV58010539; called by muse, mutect2, varscan2
- CD180 | c.881T>C p.F294S | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99842159; called by muse, mutect2, varscan2
- CD1A | c.139G>A p.G47S | Missense Mutation (SNP) | VAF 78/141 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV99192256; called by muse, mutect2, varscan2
- CD1B | c.523A>G p.T175A | Missense Mutation (SNP) | VAF 83/148 reads (56%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV100939182; called by muse, mutect2, varscan2
- CD1B | c.281G>A p.G94E | Missense Mutation (SNP) | VAF 225/446 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0.081); catalogued as COSV100939185, COSV100939241; called by muse, mutect2, varscan2
- CD1C | c.571G>A p.G191S | Missense Mutation (SNP) | VAF 218/464 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0.291); catalogued as COSV100939367; called by muse, mutect2, varscan2
- CD226 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 39/204 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.297); catalogued as rs1358404350, COSV54610640; called by muse, mutect2, varscan2
- CD274 | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.216); catalogued as rs766519356, COSV101055975; called by muse, varscan2
- CD2AP | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs761757240, COSV100830371; called by muse, varscan2
- CD36 | c.1132G>A p.G378R | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1378994947, COSV99987311; called by muse, mutect2, varscan2
- CD4 | c.1347C>T p.H449= | Splice Region (SNP) | VAF 21/124 reads (17%) | catalogued as COSV99163714; called by muse, mutect2, varscan2
- CD70 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV99835544; called by muse, mutect2
- CD86 | c.728del p.P243Qfs*18 (on ENST00000330540 / NM_175862.5; = p.P237Qfs*18 on NM_006889.4) | Frame Shift Del (DEL) | VAF 21/94 reads (22%) | catalogued as rs1442272750; called by mutect2, pindel, varscan2
- CD96 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV51913310; called by muse, mutect2, varscan2
- CD96 | c.1132T>A p.L378I (on ENST00000283285 / NM_198196.3; = p.L362I on NM_005816.5) | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.3); catalogued as COSV99342564; called by muse, mutect2, varscan2
- CDAN1 | c.2417G>A p.R806Q | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs773968503, COSV100661205; called by muse, mutect2, varscan2
- CDC20B | c.698A>G p.Y233C | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99696667; called by muse, mutect2, varscan2
- CDC34 | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1462106053, COSV53118485; called by muse, mutect2, varscan2
- CDC42BPA | c.4627C>T p.R1543C (on ENST00000334218 / NM_001366019.2; = p.R1530C on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs779106707, COSV62005872; called by muse, mutect2, varscan2
- CDC42BPB | c.3901C>A p.H1301N | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as COSV100775307; called by muse, mutect2, varscan2
- CDH11 | c.1916C>T p.T639I | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.266); catalogued as COSV51755614; called by muse, mutect2, varscan2
- CDH13 | c.1800T>G p.S600R | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV51808595, COSV99223955; called by muse, mutect2, varscan2
- CDH18 | c.7A>T p.I3F | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.07); catalogued as COSV99933097; called by muse, mutect2, varscan2
- CDH2 | c.1501C>T p.P501S | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0.005); catalogued as COSV52273109; called by muse, mutect2, varscan2
- CDH2 | c.1279C>T p.P427S | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.041); catalogued as COSV99296234, COSV99298880; called by muse, mutect2, varscan2
- CDH20 | c.1241A>G p.K414R | Missense Mutation (SNP) | VAF 39/274 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99404754; called by muse, varscan2
- CDH20 | c.2051G>A p.W684* | Nonsense Mutation (SNP) | VAF 18/89 reads (20%) | catalogued as rs1264774750, COSV99404757; called by muse, mutect2, varscan2
- CDH20 | c.2052G>A p.W684* | Nonsense Mutation (SNP) | VAF 18/89 reads (20%) | catalogued as COSV99404759, COSV99405536; called by muse, mutect2, varscan2
- CDH23 | c.8464G>A p.D2822N | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.142); catalogued as rs1305925095, COSV99819714; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDH5 | c.728C>T p.T243I | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV100439097; called by muse, mutect2, varscan2
- CDH6 | c.256G>A p.G86R | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV54080249, COSV99418452; called by muse, varscan2
- CDH6 | c.385C>T p.Q129* | Nonsense Mutation (SNP) | VAF 72/258 reads (28%) | catalogued as rs267600598, COSV99035067, COSV99418455; called by muse, varscan2
- CDH7 | c.988G>A p.D330N | Missense Mutation (SNP) | VAF 45/88 reads (51%) | SIFT tolerated (0.16); PolyPhen benign (0.402); catalogued as COSV59888680; called by muse, mutect2, varscan2
- CDH8 | c.1658A>C p.N553T | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV100180374; called by muse, mutect2, varscan2
- CDH8 | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.469); catalogued as COSV54852598; called by muse, mutect2, varscan2
- CDH9 | c.2246C>T p.S749L | Missense Mutation (SNP) | VAF 66/278 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs1161575895, COSV50265477; called by muse, mutect2, varscan2
- CDH9 | c.1543G>A p.D515N | Missense Mutation (SNP) | VAF 46/279 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1299427249, COSV99142444; called by muse, mutect2, varscan2
- CDHR2 | c.3856G>T p.G1286* | Nonsense Mutation (SNP) | VAF 19/118 reads (16%) | catalogued as COSV99991246; called by muse, mutect2, varscan2
- CDK12 | c.3871del p.Q1291Rfs*3 (on ENST00000447079 / NM_016507.4; = p.Q1282Rfs*3 on NM_015083.3) | Frame Shift Del (DEL) | VAF 23/197 reads (12%) | catalogued as COSV71000053; called by mutect2, pindel, varscan2
- CDK12 | c.4193C>T p.P1398L (on ENST00000447079 / NM_016507.4; = p.P1389L on NM_015083.3) | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1476486342, COSV101420395; called by muse, mutect2, varscan2
- CDK5 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs1445681200, COSV99876744; called by muse, mutect2, varscan2
- CDK5RAP2 | c.1148T>C p.L383P | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100575247, COSV62578521; called by muse, mutect2, varscan2
- CDSN | c.1003G>A p.G335R | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.804); catalogued as COSV99456734, COSV99456932; called by muse, mutect2, varscan2
- CEACAM4 | c.38G>A p.R13K | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as COSV55731228; called by muse, mutect2, varscan2
- CEACAM7 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 27/178 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.169); catalogued as rs1049234, COSV50073628; called by muse, mutect2, varscan2
- CEACAM8 | c.34C>T p.R12C | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs200797632, COSV99747336; called by muse, mutect2, varscan2
- CELSR3 | c.5802del p.S1935Afs*4 | Frame Shift Del (DEL) | VAF 8/47 reads (17%) | catalogued as rs1205203585, COSV50840268; called by mutect2, pindel
- CEMIP | c.1468G>A p.E490K | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54993874; called by muse, mutect2, varscan2
- CEMIP2 | c.2049+2T>C p.X683_splice | Splice Site (SNP) | VAF 20/126 reads (16%) | catalogued as COSV100987281; called by muse, mutect2, varscan2
- CENPA | c.269C>T p.A90V | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51982634; called by muse, mutect2, varscan2
- CENPE | c.3821C>T p.S1274F | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as rs779588591, COSV99477391; called by muse, mutect2, varscan2
- CEP128 | c.1666C>T p.Q556* | Nonsense Mutation (SNP) | VAF 22/80 reads (28%) | catalogued as COSV99824079; called by muse, mutect2, varscan2
- CEP131 | c.479C>T p.T160I | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as COSV99487996; called by muse, mutect2, varscan2
- CEP152 | c.355T>C p.Y119H | Missense Mutation (SNP) | VAF 54/153 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as rs1223743464, COSV57863428; called by muse, mutect2, varscan2
- CEP164 | c.2453T>C p.V818A | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99632799; called by muse, mutect2, varscan2
- CEP164 | c.3020G>A p.R1007H | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs372292887; called by muse, mutect2, varscan2
- CEP250 | c.3164C>T p.A1055V | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as rs1465113733, COSV100698824; called by muse, mutect2, varscan2
- CEP250 | c.3165C>T p.A1055= | Splice Region (SNP) | VAF 15/39 reads (38%) | catalogued as COSV100698825; called by muse, mutect2, varscan2
- CEP350 | c.8510C>T p.P2837L | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as rs1229471862, COSV100854407; called by muse, mutect2
- CEP44 | c.177G>A p.M59I | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.052); catalogued as rs1479203301, COSV99639302; called by muse, mutect2, varscan2
- CERKL | c.1407A>G p.I469M (on ENST00000339098 / NM_001030311.2; = p.I443M on NM_201548.5) | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as rs1305785438, COSV100183371; called by muse, mutect2, varscan2
- CETP | c.1322-1G>A p.X441_splice | Splice Site (SNP) | VAF 11/44 reads (25%) | catalogued as COSV99569929; called by muse, mutect2, varscan2
- CETP | c.1322G>A p.R441Q | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.441); catalogued as COSV99569931; called by muse, mutect2, varscan2
- CFAP251 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as COSV56615058; called by muse, mutect2, varscan2
- CFAP47 | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT tolerated (0.81); PolyPhen benign (0.017); catalogued as rs779460237, COSV99934292; called by muse, mutect2, varscan2
- CFAP61 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 36/238 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs373208708; called by muse, mutect2, varscan2
- CFAP69 | c.1676G>A p.G559E | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs975473625, COSV60189287; called by muse, mutect2, varscan2
- CFAP69 | c.2735C>T p.A912V | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1405277963, COSV60185413; called by muse, mutect2, varscan2
- CFHR1 | c.194C>T p.S65L | Missense Mutation (SNP) | VAF 52/94 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV100258695, COSV57627281; called by muse, mutect2, varscan2
- CFHR2 | c.265T>G p.F89V | Missense Mutation (SNP) | VAF 65/122 reads (53%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as COSV100804277, COSV66381391; called by muse, mutect2, varscan2
- CFHR5 | c.377A>G p.N126S | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV56827227; called by muse, mutect2
- CFHR5 | c.431A>T p.K144I | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as rs201787238, COSV99888251; called by muse, mutect2, varscan2
- CFI | c.1571A>G p.D524G | Missense Mutation (SNP) | VAF 114/245 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs121964914, CM041380, COSV101144231; called by muse, mutect2, varscan2
- CFTR | c.1211G>A p.G404E | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); catalogued as COSV99134692; called by muse, mutect2, varscan2
- CGA | c.220C>T p.Q74* | Nonsense Mutation (SNP) | VAF 22/110 reads (20%) | catalogued as COSV100851671; called by muse, varscan2
- CGNL1 | c.829C>T p.P277S | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs781183314, COSV55572111; called by muse, mutect2, varscan2
- CHD1 | c.3060+2T>C p.X1020_splice | Splice Site (SNP) | VAF 12/104 reads (12%) | catalogued as COSV52341674; called by muse, mutect2, varscan2
- CHD1 | c.2731C>T p.R911C | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1209284267, COSV99399248; called by muse, mutect2, varscan2
- CHD6 | c.1292T>C p.V431A | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100497954; called by muse, mutect2, varscan2
- CHIT1 | c.296G>A p.W99* | Nonsense Mutation (SNP) | VAF 30/48 reads (63%) | catalogued as rs1204615312, COSV99705131; called by muse, mutect2, varscan2
- CHKB | c.104G>A p.R35Q | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs889845523, COSV56415158; called by muse, mutect2
- CHL1 | c.3349G>A p.E1117K (on ENST00000397491 / NM_001253387.1; = p.E1133K on NM_006614.4) | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV56586966; called by muse, mutect2, varscan2
- CHPF2 | c.2246A>G p.N749S | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.288); catalogued as COSV50406692; called by muse, mutect2, varscan2
- CHRM2 | c.135G>A p.M45I | Missense Mutation (SNP) | VAF 40/186 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.241); catalogued as COSV100280945; called by muse, mutect2, varscan2
- CHRM3 | c.1700del p.K567Rfs*31 | Frame Shift Del (DEL) | VAF 46/72 reads (64%) | catalogued as rs751548647; called by mutect2, varscan2
- CHRNA4 | c.1843G>A p.V615M | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.967); catalogued as COSV100937377; called by muse, mutect2
- CHRNB2 | c.616G>A p.V206M | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.839); catalogued as rs1274001665, COSV63809279; called by muse, mutect2, varscan2
- CHRNB2 | c.932C>T p.S311F | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100872570; called by muse, mutect2, varscan2
- CHRNB3 | c.677C>T p.S226F | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.922); catalogued as rs751377779, COSV99250982; called by muse, mutect2, varscan2
- CHST10 | c.791T>C p.V264A | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0.345); catalogued as COSV99958778; called by muse, mutect2, varscan2
- CIB2 | c.82C>T p.L28F | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs768296462, COSV51949626; called by muse, mutect2, varscan2
- CIC | c.1765C>T p.R589W | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs767618694, COSV50616899, COSV99359191; called by muse, mutect2, varscan2
- CIITA | c.1802G>A p.R601Q | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0.005); catalogued as rs753947354, COSV100161590; called by mutect2, varscan2
- CILP | c.2857G>A p.A953T | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1485987629, COSV99973040; called by muse, mutect2, varscan2
- CILP2 | c.3083G>A p.R1028Q | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs929120124, COSV99364469; called by muse, mutect2
- CIPC | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.178); catalogued as COSV100694435; called by muse, mutect2, varscan2
- CKAP5 | c.3493C>T p.P1165S | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.831); catalogued as COSV100370587; called by muse, mutect2, varscan2
- CKMT2 | c.822G>A p.M274I | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs1463755006, COSV99562310; called by muse, mutect2, varscan2
- CLASP2 | c.225T>A p.S75R | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as rs1382210538, COSV100222878; called by muse, mutect2
- CLASP2 | c.224G>A p.S75N | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.639); catalogued as rs1246812011, COSV100222880; called by muse, mutect2
- CLCA1 | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.14); catalogued as COSV99322067; called by muse, mutect2, varscan2
- CLEC18B | c.459C>T p.L153= | Splice Region (SNP) | VAF 15/121 reads (12%) | catalogued as rs546829879, COSV100375806; called by muse, mutect2, varscan2
- CLEC18B | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.45); PolyPhen benign (0.014); catalogued as COSV100375809; called by muse, varscan2
- CLEC3A | c.40G>A p.G14R (on ENST00000651443; = p.G5R on NM_005752.6) | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.207); catalogued as COSV100222129; called by muse, mutect2
- CLEC4E | c.634C>T p.P212S | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV100222699, COSV55225075; called by muse, mutect2, varscan2
- CLEC4E | c.215G>A p.G72E | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.031); catalogued as COSV100222565; called by muse, mutect2, varscan2
- CLIC6 | c.1678G>A p.G560R (on ENST00000360731 / NM_001317009.2; = p.G542R on NM_053277.3) | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs557961265, COSV100659162; called by muse, mutect2, varscan2
- CLIP1 | c.1758G>T p.K586N (on ENST00000620786 / NM_001247997.1; = p.K575N on NM_002956.2) | Missense Mutation (SNP) | VAF 100/254 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.244); catalogued as COSV100211421, COSV56798019; called by muse, mutect2, varscan2
- CLIP2 | c.1883T>G p.L628R | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV99791218; called by muse, mutect2, varscan2
- CLIP2 | c.1984C>G p.L662V | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.991); catalogued as COSV99791220; called by muse, mutect2, varscan2
- CLIP4 | c.1675G>A p.D559N | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.903); catalogued as rs371931731; called by muse, mutect2, varscan2
- CLPX | c.505C>G p.P169A | Missense Mutation (SNP) | VAF 56/214 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100269381; called by muse, mutect2, varscan2
- CLSTN2 | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.537); catalogued as COSV101515600; called by muse, mutect2, varscan2
- CLSTN3 | c.1306C>T p.L436F | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.932); catalogued as rs1565650078, COSV99866705; called by muse, mutect2, varscan2
- CLTCL1 | c.1819C>T p.H607Y | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.911); catalogued as COSV99594717; called by muse, mutect2, varscan2
- CMSS1 | c.170del p.L57* | Frame Shift Del (DEL) | VAF 10/22 reads (45%) | catalogued as rs1473145983; called by mutect2, pindel, varscan2
- CMYA5 | c.7024G>A p.D2342N | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as rs1216954169, COSV101483953, COSV71405101, COSV71410215; called by muse, mutect2, varscan2
- CNGA1 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0.073); catalogued as COSV62052962; called by muse, mutect2, varscan2
- CNOT1 | c.4160C>T p.P1387L | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); catalogued as COSV99799608; called by muse, mutect2, varscan2
- CNOT3 | c.1334G>A p.S445N | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs1280596106, COSV99651629; called by muse, mutect2, varscan2
- CNOT9 | c.106G>T p.E36* | Nonsense Mutation (SNP) | VAF 23/91 reads (25%) | catalogued as COSV99813646; called by muse, mutect2, varscan2
- CNR1 | c.374C>T p.T125M | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.386); catalogued as rs967383969, COSV100759164, COSV62986321; called by muse, mutect2, varscan2
- CNR2 | c.707G>A p.R236Q | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.441); catalogued as rs567833720, COSV65692174; called by muse, mutect2, varscan2
- CNTN2 | c.794G>A p.G265E | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100084790, COSV59350205; called by muse, mutect2, varscan2
- CNTN2 | c.2482G>A p.E828K | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV100084793; called by muse, mutect2, varscan2
- CNTN4 | c.515T>C p.V172A | Missense Mutation (SNP) | VAF 61/195 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV61876606; called by muse, mutect2, varscan2
- CNTN5 | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.486); catalogued as rs1489941088, COSV54278175; called by muse, mutect2, varscan2
- CNTN5 | c.2467G>A p.E823K | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.996); catalogued as rs1385144818, COSV54282815, COSV99680319; called by muse, mutect2
- CNTN6 | c.3058C>T p.H1020Y | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100610392; called by muse, mutect2, varscan2
- CNTRL | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53046791; called by muse, mutect2, varscan2
- COBLL1 | c.2908C>T p.P970S (on ENST00000392717; = p.P932S on NM_014900.5) | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.69); PolyPhen benign (0.027); catalogued as rs765158775, COSV52073853; called by muse, mutect2, varscan2
- COG1 | c.1205T>A p.L402Q | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV100245223; called by muse, mutect2, varscan2
- COG5 | c.2096G>A p.R699K (on ENST00000347053 / NM_001379512.1; = p.R720K on NM_006348.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/267 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV99771665; called by muse, mutect2, varscan2
- COL10A1 | c.406G>A p.G136R | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99684129; called by muse, mutect2, varscan2
- COL11A1 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 54/98 reads (55%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.905); catalogued as rs1341498364, COSV62186825; called by muse, mutect2, varscan2
- COL11A2 | c.1825C>T p.R609* (on ENST00000341947 / NM_080680.3; = p.R502* on NM_080679.2) | Nonsense Mutation (SNP) | VAF 15/35 reads (43%) | catalogued as rs766082539, COSV100553631; called by muse, mutect2, varscan2
- COL14A1 | c.4873G>A p.E1625K | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs866412093, COSV99918290; called by muse, mutect2, varscan2
- COL14A1 | c.5105G>A p.G1702E | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52850614; called by muse, mutect2, varscan2
- COL19A1 | c.1244G>A p.G415E | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV100505750; called by muse, mutect2, varscan2
- COL19A1 | c.3362G>A p.G1121E | Missense Mutation (SNP) | VAF 50/296 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100505752; called by muse, varscan2
- COL1A1 | c.4183G>A p.E1395K | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as rs373474549, COSV56805168; called by muse, mutect2, varscan2
- COL1A2 | c.3121C>T p.Q1041* | Nonsense Mutation (SNP) | VAF 6/33 reads (18%) | catalogued as COSV99799040; called by muse, mutect2, varscan2
- COL22A1 | c.2539C>T p.P847S | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.968); catalogued as COSV100277190; called by muse, varscan2
- COL22A1 | c.2518G>T p.G840C | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV100277192, COSV57345150; called by muse, varscan2
- COL25A1 | c.1767G>T p.G589= | Splice Region (SNP) | VAF 23/134 reads (17%) | catalogued as COSV101211276; called by muse, mutect2, varscan2
- COL25A1 | c.746G>A p.G249E | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101211277; called by muse, mutect2, varscan2
- COL25A1 | c.745G>A p.G249R | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101211278; called by muse, mutect2, varscan2
- COL28A1 | c.829G>A p.G277R | Missense Mutation (SNP) | VAF 44/187 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101258422; called by muse, mutect2, varscan2
- COL2A1 | c.724del p.R242Vfs*66 | Frame Shift Del (DEL) | VAF 9/68 reads (13%) | catalogued as CD103304, COSV100477780; called by mutect2, pindel, varscan2
- COL3A1 | c.1322G>A p.G441E | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100482719; called by muse, mutect2, varscan2
- COL4A2 | c.1600G>T p.V534L | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.87); PolyPhen benign (0.014); catalogued as COSV100847285; called by muse, mutect2
- COL4A3 | c.2890G>A p.G964R | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1446680986, COSV100516683; called by muse, mutect2, varscan2
- COL4A3 | c.3433C>T p.P1145S | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.15); catalogued as rs1210914620, COSV100516684; called by muse, varscan2
- COL4A4 | c.3787C>T p.Q1263* | Nonsense Mutation (SNP) | VAF 8/31 reads (26%) | catalogued as COSV61632295; called by mutect2, varscan2
- COL4A4 | c.509G>A p.G170E | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100306461; called by muse, mutect2, varscan2
- COL4A5 | c.242G>A p.G81E | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60370462; called by muse, varscan2
- COL4A5 | c.3214A>G p.S1072G | Missense Mutation (SNP) | VAF 47/72 reads (65%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100087057; called by muse, mutect2, varscan2
- COL5A1 | c.1057G>A p.D353N | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as rs868061456, COSV100879700; called by muse, mutect2, varscan2
- COL5A1 | c.4292C>T p.P1431L | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV65677357; called by muse, mutect2
- COL5A1 | c.4361C>T p.S1454F | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.28); catalogued as rs781445285, COSV65670696; called by muse, mutect2, varscan2
- COL6A5 | c.6364G>A p.D2122N (on ENST00000312481; = p.D2118N on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.037); catalogued as rs775009506, COSV55216877; called by muse, mutect2, varscan2
- COL6A6 | c.5081G>A p.R1694K | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100650048; called by muse, mutect2, varscan2
- COL8A1 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as rs766271324, COSV53742422; called by muse, mutect2, varscan2
- COL8A1 | c.919C>T p.Q307* | Nonsense Mutation (SNP) | VAF 10/41 reads (24%) | catalogued as COSV99657390; called by muse, mutect2, varscan2
- COL8A2 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.646); catalogued as rs776813844, COSV57442924; called by muse, varscan2
- COL9A1 | c.932G>A p.G311E | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as COSV57890147; called by muse, mutect2, varscan2
- COL9A1 | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV100294343; called by muse, mutect2, varscan2
- COLQ | c.605T>C p.F202S | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0.021); catalogued as COSV101082113; called by muse, mutect2, varscan2
- COQ6 | c.1267C>T p.L423F | Missense Mutation (SNP) | VAF 56/235 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.516); catalogued as COSV99473820, COSV99473989; called by muse, mutect2, varscan2
- CORO2B | c.806G>A p.G269E | Missense Mutation (SNP) | VAF 73/226 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.366); catalogued as COSV99963051; called by muse, mutect2, varscan2
- CPA3 | c.914C>T p.S305F | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56046401; called by muse, mutect2, varscan2
- CPAMD8 | c.4742G>A p.G1581E (on ENST00000651564; = p.G1534E on NM_015692.5) | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated (0.91); PolyPhen possibly damaging (0.744); catalogued as COSV71596822; called by muse, mutect2, varscan2
- CPAMD8 | c.3349C>A p.P1117T (on ENST00000651564; = p.P1070T on NM_015692.5) | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.991); catalogued as COSV101488443; called by muse, mutect2, varscan2
- CPB1 | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.61); catalogued as rs765630651, COSV51575445; called by muse, mutect2, varscan2
- CPB1 | c.1126A>C p.T376P | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV99294148; called by muse, mutect2, varscan2
- CPE | c.563A>G p.N188S | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV101291559; called by muse, mutect2, varscan2
- CPE | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 53/214 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.298); catalogued as rs753892074, COSV68579204; called by muse, mutect2, varscan2
- CPED1 | c.2758A>T p.I920F | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100120346; called by muse, mutect2, varscan2
- CPNE4 | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.165); catalogued as COSV101456771, COSV70196761; called by muse, mutect2, varscan2
- CPNE4 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as COSV70198839; called by muse, mutect2, varscan2
- CPNE4 | c.214A>T p.N72Y | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as COSV101456604; called by muse, mutect2, varscan2
- CPO | c.917C>T p.S306L | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV55938526, COSV99786411; called by muse, mutect2, varscan2
- CPS1 | c.3743G>A p.G1248E | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.669); catalogued as rs1243506295, COSV51810934; called by muse, mutect2
- CPT1C | c.1033G>A p.G345R | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0.151); catalogued as COSV54919260; called by muse, mutect2, varscan2
- CPXCR1 | c.120G>A p.M40I | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1005317634, COSV99342069; called by muse, mutect2, varscan2
- CPZ | c.829C>T p.Q277* (on ENST00000360986 / NM_001014447.3; = p.Q266* on NM_003652.3) | Nonsense Mutation (SNP) | VAF 19/43 reads (44%) | catalogued as COSV100248857; called by muse, mutect2, varscan2
- CR1 | c.2354C>A p.A785D | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as COSV100887465; called by mutect2, varscan2
- CR2 | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs147633291; called by muse, mutect2, varscan2
- CRAT | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as rs1294248689, COSV100533966; called by muse, mutect2, varscan2
- CRB1 | c.1976C>T p.S659L | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as rs986645649, COSV66328552; called by muse, mutect2, varscan2
- CRCT1 | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 8/23 reads (35%) | PolyPhen possibly damaging (0.823); catalogued as rs1275697279, COSV57501274; called by muse, mutect2, varscan2
- CREB3L1 | c.616C>T p.P206S | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as rs1312790484, COSV99914900; called by muse, mutect2, varscan2
- CREB3L3 | c.127G>A p.G43S | Missense Mutation (SNP) | VAF 41/79 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.449); catalogued as COSV99313986; called by muse, mutect2, varscan2
- CREBBP | c.4384A>G p.K1462E | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV99269147; called by muse, mutect2, varscan2
- CRHR1 | c.554G>A p.W185* (on ENST00000398285 / NM_001145146.2; = p.W156* on NM_004382.5) | Nonsense Mutation (SNP) | VAF 27/108 reads (25%) | catalogued as COSV99523411; called by muse, mutect2, varscan2
- CRHR1 | c.555G>A p.W185* (on ENST00000398285 / NM_001145146.2; = p.W156* on NM_004382.5) | Nonsense Mutation (SNP) | VAF 27/106 reads (25%) | catalogued as COSV99523412; called by muse, mutect2, varscan2
- CRISP1 | c.403G>A p.D135N | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.147); catalogued as COSV59995341; called by muse, mutect2, varscan2
- CRISP3 | c.157G>A p.E53K (on ENST00000371159 / NM_001368123.1; = p.E35K on NM_006061.4) | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.77); PolyPhen benign (0.005); catalogued as COSV53820359; called by muse, mutect2, varscan2
- CRNKL1 | c.1456-1G>A p.X486_splice | Splice Site (SNP) | VAF 53/136 reads (39%) | catalogued as COSV101056908, COSV101057139; called by muse, mutect2, varscan2
- CRNN | c.446G>A p.R149K | Missense Mutation (SNP) | VAF 53/264 reads (20%) | SIFT tolerated (0.96); PolyPhen benign (0.104); catalogued as COSV99664009; called by muse, mutect2, varscan2
- CRTC1 | c.1713del p.S572Afs*6 | Frame Shift Del (DEL) | VAF 9/80 reads (11%) | catalogued as rs769538822; called by mutect2, varscan2
- CRYBG2 | c.3290C>T p.S1097F | Missense Mutation (SNP) | VAF 80/168 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0.32); catalogued as COSV100366470; called by muse, mutect2, varscan2
- CRYBG3 | c.7231C>T p.P2411S | Missense Mutation (SNP) | VAF 70/177 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as rs1451338226, COSV99476759; called by muse, mutect2, varscan2
- CRYM | c.617T>C p.L206P | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.11); catalogued as COSV99561649; called by muse, varscan2
- CRYM | c.569C>T p.S190L | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs757696626, COSV99561653; called by muse, varscan2
- CRYM | c.568T>G p.S190A | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.467); catalogued as COSV99561655; called by muse, varscan2
- CSF2RA | c.674C>T p.T225I | Missense Mutation (SNP) | VAF 76/242 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100817584; called by muse, mutect2, varscan2
- CSMD1 | c.7804C>T p.R2602W (on ENST00000520002; = p.R2601W on NM_033225.6) | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as rs371779170; called by mutect2, varscan2
- CSMD1 | c.3866G>A p.R1289Q (on ENST00000520002; = p.R1288Q on NM_033225.6) | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.99); catalogued as rs780978438, COSV59300261, COSV59344665; called by muse, mutect2, varscan2
- CSMD1 | c.3341G>A p.G1114E (on ENST00000520002; = p.G1113E on NM_033225.6) | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs369837551, COSV100147135; called by muse, mutect2, varscan2
- CSMD1 | c.3181C>T p.H1061Y (on ENST00000520002; = p.H1060Y on NM_033225.6) | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.182); catalogued as COSV59325986; called by muse, mutect2, varscan2
- CSMD2 | c.9419G>A p.G3140E | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99587533; called by muse, varscan2
- CSMD2 | c.8485+1G>A p.X2829_splice | Splice Site (SNP) | VAF 33/85 reads (39%) | catalogued as rs1236056604, COSV53922824, COSV99587535; called by muse, mutect2, varscan2
- CSMD3 | c.9958C>T p.P3320S (on ENST00000297405 / NM_001363185.1; = p.P3151S on NM_052900.3) | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.124); catalogued as COSV52271134; called by muse, mutect2, varscan2
- CSMD3 | c.8816C>T p.P2939L (on ENST00000297405 / NM_001363185.1; = p.P2770L on NM_052900.3) | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT tolerated (0.35); PolyPhen probably damaging (1); catalogued as COSV52160957; called by muse, mutect2, varscan2
- CSMD3 | c.8606C>T p.S2869F (on ENST00000297405 / NM_001363185.1; = p.S2700F on NM_052900.3) | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.648); catalogued as COSV99828977; called by muse, mutect2, varscan2
- CSMD3 | c.8212G>A p.E2738K | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.269); catalogued as rs1283805790, COSV52092220; called by muse, mutect2, varscan2
- CSNK1D | c.497C>A p.P166H | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV99484432; called by muse, mutect2, varscan2
- CSNK1G2 | c.68G>A p.G23E | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.338); catalogued as COSV55336647; called by muse, mutect2, varscan2
- CSNK1G3 | c.1147C>T p.H383Y | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.102); catalogued as COSV100631398; called by muse, mutect2, varscan2
- CST2 | c.425A>T p.*142Lext*79 | Nonstop Mutation (SNP) | VAF 9/56 reads (16%) | catalogued as COSV100491159; called by muse, mutect2, varscan2
- CT45A10 | c.344C>T p.S115F | Missense Mutation (SNP) | VAF 111/167 reads (66%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100867525; called by muse, mutect2, varscan2
- CT55 | c.262G>A p.G88R | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV99358821; called by muse, mutect2, varscan2
- CTAGE1 | c.1333G>A p.D445N | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.162); catalogued as COSV101194469; called by muse, mutect2, varscan2
- CTAGE6 | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 62/267 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs778979165, COSV69919016; called by muse, mutect2, varscan2
- CTAGE6 | c.989G>A p.S330N | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.088); catalogued as rs765086169, COSV101417827; called by muse, mutect2, varscan2
- CTDNEP1 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as rs1183808076, COSV100020873; called by muse, mutect2
- CTNNA1 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 57/146 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.222); catalogued as rs780367865, COSV100242405; called by muse, mutect2, varscan2
- CTPS1 | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.651); catalogued as rs1305511593, COSV101009304; called by muse, mutect2, varscan2
- CUL1 | c.952+2T>G p.X318_splice | Splice Site (SNP) | VAF 14/92 reads (15%) | catalogued as COSV100296527; called by muse, mutect2, varscan2
- CUL5 | c.910C>T p.P304S | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs1288167795, COSV67609447; called by muse, mutect2, varscan2
- CUX2 | c.1024C>T p.L342F | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs764359441, COSV99919065; called by muse, mutect2, varscan2
- CUX2 | c.1619G>A p.G540E | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV99919069; called by muse, mutect2, varscan2
- CUX2 | c.3065C>A p.S1022* | Nonsense Mutation (SNP) | VAF 12/44 reads (27%) | catalogued as COSV55647710, COSV99919073; called by muse, mutect2, varscan2
- CWC27 | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1434281558, COSV101126468; called by muse, mutect2, varscan2
- CWH43 | c.357-2A>T p.X119_splice | Splice Site (SNP) | VAF 15/88 reads (17%) | catalogued as COSV99893066; called by muse, mutect2, varscan2
- CWH43 | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs369610807; called by muse, mutect2, varscan2
- CWH43 | c.1102C>T p.P368S | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as rs1176981680, COSV56942410; called by muse, mutect2, varscan2
- CWH43 | c.1286C>T p.S429F | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as rs868306552; called by muse, mutect2
- CWH43 | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 51/108 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as rs751413481, COSV56936054; called by muse, mutect2, varscan2
- CXCL9 | c.340C>T p.R114* | Nonsense Mutation (SNP) | VAF 14/103 reads (14%) | catalogued as rs757038649, COSV53578638; called by muse, mutect2, varscan2
- CYBA | c.274G>A p.V92I | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs202179890, COSV55368574; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CYBB | c.58G>A p.G20R | Missense Mutation (SNP) | VAF 34/45 reads (76%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as CM093011, CM960430, COSV101059712, COSV101059751; called by muse, mutect2, varscan2
- CYBB | c.628C>T p.H210Y | Missense Mutation (SNP) | VAF 50/80 reads (63%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV101059714; called by muse, mutect2, varscan2
- CYLC1 | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as rs1487428850, COSV100254309; called by muse, varscan2
- CYP11B1 | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs754240896, COSV52825008, COSV52827933; called by muse, mutect2, varscan2
- CYP11B1 | c.964C>T p.P322S | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.329); catalogued as COSV52830232; called by muse, mutect2
- CYP26B1 | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50015505, COSV99134366; called by muse, mutect2
- CYP2A6 | c.1144G>A p.D382N | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV99991773; called by muse, mutect2, varscan2
- CYP2B6 | c.323T>G p.F108C | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV100137388; called by muse, mutect2, varscan2
- CYP2W1 | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.14); catalogued as COSV100417137; called by muse, mutect2
- CYP3A43 | c.1492G>A p.G498R (on ENST00000354829 / NM_057095.3; = p.G499R on NM_022820.5) | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.046); catalogued as rs1259773525, COSV99733046; called by muse, mutect2, varscan2
- CYP3A5 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as COSV56118765, COSV99769599; called by muse, mutect2, varscan2
- CYP3A7 | c.1223G>A p.W408* | Nonsense Mutation (SNP) | VAF 31/99 reads (31%) | catalogued as COSV60481273; called by muse, mutect2, varscan2
- CYP4F12 | c.1378C>T p.P460S | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV61177175; called by muse, mutect2, varscan2
- CYP4F2 | c.1250G>A p.G417D | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99685816; called by muse, mutect2, varscan2
- CYP4F8 | c.645G>A p.Q215= | Splice Region (SNP) | VAF 14/50 reads (28%) | catalogued as rs1261691497, COSV100358059; called by muse, mutect2, varscan2
- CYTH2 | c.734T>G p.I245S | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.848); catalogued as COSV100287101; called by muse, mutect2, varscan2
- CYTH3 | c.905A>T p.D302V (on ENST00000396741; = p.D301V on NM_004227.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV100084117; called by muse, varscan2
- CYTIP | c.991A>G p.K331E | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV99938678; called by muse, mutect2, varscan2
- DAAM2 | c.2230C>T p.R744C | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750202686, COSV99224976; called by mutect2, varscan2
- DAB1 | c.742G>A p.D248N | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.022); catalogued as rs767870898, COSV100976210; called by mutect2, varscan2
- DAB1 | c.532A>T p.K178* | Nonsense Mutation (SNP) | VAF 35/153 reads (23%) | catalogued as rs1475158202, COSV100139651, COSV100139744; called by muse, mutect2, varscan2
- DACT3 | c.1844T>A p.I615K | Missense Mutation (SNP) | VAF 80/382 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100340216; called by muse, mutect2
- DAGLA | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV99944143; called by muse, mutect2, varscan2
- DBF4 | c.1898G>A p.G633D | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99719207; called by muse, mutect2, varscan2
- DCAF4L2 | c.485C>T p.S162L | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.963); catalogued as rs748853957, COSV100150629, COSV60480352; called by muse, mutect2, varscan2
- DCAF8 | c.842A>G p.Q281R | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.626); catalogued as COSV100470261; called by muse, mutect2, varscan2
- DCANP1 | c.614C>T p.S205L | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.021); catalogued as rs534209085, COSV72345937; called by muse, mutect2, varscan2
- DCANP1 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.013); catalogued as COSV101538229; called by muse, mutect2, varscan2
- DCC | c.1289C>T p.S430L | Missense Mutation (SNP) | VAF 37/170 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs563504489, COSV100498921; called by muse, mutect2, varscan2
- DCC | c.3439G>A p.D1147N | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs148589863; called by muse, mutect2, varscan2
- DCHS1 | c.1670del p.P557Lfs*2 | Frame Shift Del (DEL) | VAF 26/97 reads (27%) | catalogued as COSV55044235; called by mutect2, pindel, varscan2
- DCHS1 | c.643C>T p.R215* | Nonsense Mutation (SNP) | VAF 38/80 reads (48%) | catalogued as rs747608620, COSV55035631; called by muse, mutect2, varscan2
- DCUN1D3 | c.653C>T p.P218L | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100176703; called by muse, mutect2, varscan2
- DCX | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV100576289; called by muse, mutect2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 30/82 reads (37%) | catalogued as rs766714372; called by mutect2, varscan2
- DDX39A | c.1089G>A p.M363I | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.343); catalogued as COSV99660207; called by muse, mutect2, varscan2
- DDX3Y | c.1829G>A p.G610D | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as COSV100267498; called by muse, mutect2, varscan2
- DDX4 | c.1066A>G p.T356A | Missense Mutation (SNP) | VAF 39/163 reads (24%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.996); catalogued as COSV100737407; called by muse, mutect2, varscan2
- DDX56 | c.883C>T p.R295C | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs200177535, COSV99345994; called by muse, mutect2, varscan2
- DDX6 | c.871C>T p.H291Y | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT tolerated (0.68); PolyPhen benign (0.021); catalogued as COSV99870190; called by muse, mutect2, varscan2
- DDX60L | c.2186G>A p.R729K | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV99487203; called by muse, mutect2, varscan2
- DEFB110 | c.158T>G p.I53S | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV100953753; called by muse, mutect2, varscan2
- DEFB112 | c.161C>T p.S54L | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.458); catalogued as rs867941522, COSV59182489; called by muse, mutect2, varscan2
- DEFB119 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 19/115 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as rs267605872, COSV59266560; called by muse, mutect2, varscan2
- DEGS1 | c.817C>T p.L273F | Missense Mutation (SNP) | VAF 57/113 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100083312; called by muse, varscan2
- DEK | c.453A>G p.K151= | Splice Region (SNP) | VAF 36/99 reads (36%) | catalogued as rs755361234, COSV99788774; called by muse, mutect2, varscan2
- DENND11 | c.936G>T p.E312D | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.085); catalogued as COSV101530704; called by muse, mutect2
- DENND6A | c.530G>A p.S177N | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs867389653, COSV100231373; called by muse, mutect2
- DENND6B | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); catalogued as COSV101306043; called by muse, mutect2, varscan2
- DEUP1 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV53209815; called by muse, mutect2, varscan2
- DGAT2L6 | c.880C>T p.P294S | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60719063; called by muse, mutect2, varscan2
- DGKB | c.892T>C p.Y298H | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as COSV99337704; called by muse, mutect2
- DGKD | c.3423G>A p.P1141= (on ENST00000264057 / NM_152879.3; = p.P1097= on NM_003648.3 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 58/174 reads (33%) | catalogued as rs551689131, COSV99895820; called by muse, mutect2, varscan2
- DGKG | c.1820A>G p.N607S | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.781); catalogued as rs1264288012, COSV99402848; called by muse, mutect2, varscan2
- DGKI | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 49/147 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1188626720, COSV99933081; called by muse, mutect2, varscan2
- DHCR7 | c.1319T>C p.L440P | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100831814; called by muse, mutect2, varscan2
- DHRS2 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 52/119 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.617); catalogued as COSV99158875; called by muse, mutect2, varscan2
- DHRS2 | c.699G>A p.W233* | Nonsense Mutation (SNP) | VAF 20/54 reads (37%) | catalogued as rs752822666, COSV99158879; called by muse, varscan2
- DHRS2 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.74); PolyPhen benign (0.007); catalogued as COSV99158880; called by muse, varscan2
- DHRS7 | c.718A>T p.N240Y | Missense Mutation (SNP) | VAF 52/143 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV99381547; called by muse, mutect2, varscan2
- DHRSX | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.871); catalogued as rs139175675, COSV58134753; called by muse, mutect2, varscan2
- DHX30 | c.1028G>A p.R343H (on ENST00000445061 / NM_138615.3; = p.R304H on NM_014966.3) | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV99274923; called by muse, mutect2, varscan2
- DHX36 | c.1568C>T p.P523L | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1395162267, COSV100273434; called by muse, mutect2, varscan2
- DHX36 | c.1567C>T p.P523S | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs776349643, COSV100273435; called by muse, mutect2, varscan2
- DHX40 | c.1157C>T p.S386L | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1200953377, COSV99232826; called by muse, mutect2, varscan2
- DHX57 | c.2909C>T p.S970F | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs771116019, COSV54885950, COSV99769225; called by muse, mutect2, varscan2
- DHX9 | c.2086C>T p.R696C | Missense Mutation (SNP) | VAF 49/98 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100841304; called by muse, mutect2, varscan2
- DICER1 | c.4865C>A p.A1622D | Missense Mutation (SNP) | VAF 148/342 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.261); catalogued as COSV100601901; called by muse, mutect2, varscan2
- DIP2B | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV56583305; called by muse, mutect2, varscan2
- DIP2C | c.622C>T p.P208S | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as COSV55145590, COSV55154790; called by muse, mutect2, varscan2
- DIPK2B | c.761A>G p.Q254R | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV101211643; called by muse, mutect2
- DIRAS3 | c.478G>T p.E160* | Nonsense Mutation (SNP) | VAF 77/171 reads (45%) | catalogued as COSV100921307; called by muse, mutect2, varscan2
- DIRAS3 | c.337G>A p.V113I | Missense Mutation (SNP) | VAF 27/224 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as COSV63970408; called by muse, mutect2, varscan2
- DIS3L | c.2782C>T p.R928* (on ENST00000319212 / NM_001143688.3; = p.R845* on NM_133375.5 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 27/87 reads (31%) | catalogued as rs768551036, COSV99972298; called by muse, mutect2, varscan2
- DKK2 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as COSV53401085; called by muse, mutect2, varscan2
- DLEC1 | c.673G>A p.G225S | Missense Mutation (SNP) | VAF 61/175 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.295); catalogued as rs533245447, COSV100341771; called by muse, mutect2, varscan2
- DLG5 | c.4088C>T p.S1363F | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100967337; called by muse, mutect2, varscan2
- DLG5 | c.3526+2T>C p.X1176_splice | Splice Site (SNP) | VAF 9/138 reads (7%) | catalogued as COSV64950682; called by muse, mutect2
- DMBT1 | c.2392G>A p.D798N | Missense Mutation (SNP) | VAF 106/176 reads (60%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.726); catalogued as COSV100352504, COSV100353139; called by muse, mutect2, varscan2
- DMD | c.10627C>T p.P3543S | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.917); catalogued as COSV100626428; called by muse, mutect2, varscan2
3,863 further variants in this file (2,311 protein-altering or splice-affecting, 1,444 silent, 108 other) are not listed here.
